Somatic mutation profile of tumor specimen 0DJGE1 from CCDI case PBBWVB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.1 years (4,793 days).
Specimen 0DJGE1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d6b7fcf-9422-4242-89a1-44d65e1ff688.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJG70 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/87477dd7-7345-45db-b1f7-76a28ccb17e9

The open-access MAF lists 16,057 somatic variants for this specimen: 9,765 protein-altering or splice-affecting, 3,450 silent, 2,842 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8,690, Silent 3,450, Intron 1,622, 3'UTR 692, Nonsense Mutation 493, 5'UTR 325, Splice Region 193, Splice Site 159, Frame Shift Del 128, Frame Shift Ins 88, 5'Flank 77, RNA 67.

Variants (750 of 16,057; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AAAS | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 37/291 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs758440592, CM055898, CM065946, COSV52932932; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ALG8 | c.396dup p.V133Sfs*3 | Frame Shift Ins (INS) | VAF 68/376 reads (18%) | catalogued as rs753631154; ClinVar: pathogenic; called by mutect2, varscan2
- ALMS1 | c.10822C>T p.R3608* | Nonsense Mutation (SNP) | VAF 359/1169 reads (31%) | catalogued as rs1192396248, CM074692, COSV100041495; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARHGEF9 | c.865C>T p.R289* | Nonsense Mutation (SNP) | VAF 423/627 reads (67%) | catalogued as rs1135401795, COSV53636533; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BAG3 | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 136/373 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121918312, CM090724, COSV64842767; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- CA5A | c.94C>T p.R32* | Nonsense Mutation (SNP) | VAF 157/437 reads (36%) | catalogued as rs767402215, COSV59239468; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CDC45 | c.1021C>T p.R341W | Missense Mutation (SNP) | VAF 249/718 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs540900837, COSV54243701; ClinVar: likely pathogenic; called by muse, varscan2
- CFTR | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 381/1053 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs77932196, CM900044, CM920152, CM930105, COSV50066714; ClinVar: drug response / pathogenic; called by muse, mutect2, varscan2
- COL5A1 | c.2897del p.P966Lfs*108 | Frame Shift Del (DEL) | VAF 94/313 reads (30%) | catalogued as rs1179967153; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- DIS3 | c.2066G>A p.R689Q | Missense Mutation (SNP) | VAF 153/1065 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV66706044; called by muse, mutect2, varscan2
- DYNC1H1 | c.6994C>T p.R2332C | Missense Mutation (SNP) | VAF 233/733 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057518961, CM152587, COSV64135056; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DYRK1A | c.1309C>T p.R437* | Nonsense Mutation (SNP) | VAF 371/1166 reads (32%) | catalogued as rs724159953, CM1510739, COSV58292386; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.6453C>T p.C2151= | Silent (SNP) | VAF 426/1237 reads (34%) | catalogued as rs794728251, CM940769, CS118012, COSV57318600; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.442+1G>A p.X148_splice | Splice Site (SNP) | VAF 440/1296 reads (34%) | catalogued as rs868403743; ClinVar: likely pathogenic; called by muse, varscan2
- FH | c.301C>T p.R101* | Nonsense Mutation (SNP) | VAF 503/1433 reads (35%) | catalogued as rs121913120, CD1511505, CM020700; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GALC | c.1592G>A p.R531H | Missense Mutation (SNP) | VAF 563/1618 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs200378205, CM990620, COSV54325031; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GLDC | c.2216G>A p.R739H | Missense Mutation (SNP) | VAF 254/889 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121964980, CM051081; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GLRA1 | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 87/483 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs199547699, CM104312, COSV51010888; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- HEXA | c.1511G>A p.R504H | Missense Mutation (SNP) | VAF 171/469 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121907955, CM123435, CM900128, COSV51506212; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- HPS3 | c.1189C>T p.R397W | Missense Mutation (SNP) | VAF 160/845 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs121908316, CM013270, COSV56052762; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- IL12RB1 | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 105/309 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs121434494, CM011788, COSV59098771; ClinVar: pathogenic; called by muse, mutect2, varscan2
- INPP5E | c.1754G>A p.R585H | Missense Mutation (SNP) | VAF 162/448 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752300607; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KARS1 | c.1493C>T p.A498V | Missense Mutation (SNP) | VAF 273/850 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1415687857, COSV56691858; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- KCNQ1 | c.1747C>T p.R583C | Missense Mutation (SNP) | VAF 135/390 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs17221854, CM002334, CM142066; ClinVar: pathogenic / not provided / risk factor / likely pathogenic; called by muse, mutect2, varscan2
- KMT2A | c.478C>T p.R160* | Nonsense Mutation (SNP) | VAF 193/561 reads (34%) | catalogued as rs1555034779, COSV100627800; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KMT2A | c.3190C>T p.R1064* | Nonsense Mutation (SNP) | VAF 34/774 reads (4%) | catalogued as rs1555037629, COSV63292691; ClinVar: pathogenic; called by muse, mutect2
- L1CAM | c.924C>T p.G308= | Silent (SNP) | VAF 22/302 reads (7%) | catalogued as rs797044787, CS982242, COSV100648896; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- MAP3K7 | c.617A>G p.Y206C | Missense Mutation (SNP) | VAF 231/674 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1554184177, COSV65226239; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MTHFD1 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 106/315 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs141210410, CM116771; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MTHFR | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 119/403 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs574132670, CM155651, COSV64701534, COSV64701602; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- NEXMIF | c.937C>T p.R313* | Nonsense Mutation (SNP) | VAF 183/572 reads (32%) | catalogued as rs878854425, COSV50022161; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.4110+1G>A p.X1370_splice | Splice Site (SNP) | VAF 233/648 reads (36%) | catalogued as rs1555617383, CS000898, CS971829, COSV62193545, COSV62207614; ClinVar: pathogenic; called by muse, mutect2, varscan2
- OPA1 | c.740G>A p.R247H (on ENST00000361510 / NM_130837.3; = p.R211H on NM_130832.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 593/1697 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs138350727, CM081724; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- OTOF | c.2122C>T p.R708* | Nonsense Mutation (SNP) | VAF 118/359 reads (33%) | catalogued as rs80356590, CM033478; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3062A>G p.Y1021C | Missense Mutation (SNP) | VAF 283/1540 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913288, CM126695, COSV55882161, COSV55997924; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- POLR3A | c.1114G>A p.D372N | Missense Mutation (SNP) | VAF 254/727 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs267608673, CM117047; ClinVar: pathogenic; called by muse, varscan2
- PSMD12 | c.544C>T p.R182* | Nonsense Mutation (SNP) | VAF 66/998 reads (7%) | catalogued as rs1567954436, COSV100635438; ClinVar: pathogenic; called by muse, mutect2
- PTEN | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 206/643 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs121913293, CM074467, COSV64288569, COSV64310838; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RS1 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 231/282 reads (82%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs61752158, CM981754, CM981755, HD080013; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SGSH | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 132/390 reads (34%) | catalogued as rs374621913, CM002395; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SHANK3 | c.2244+1G>A p.X748_splice | Splice Site (SNP) | VAF 150/422 reads (36%) | catalogued as rs1396379503; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SLC25A13 | c.1813C>T p.R605* | Nonsense Mutation (SNP) | VAF 68/1143 reads (6%) | catalogued as rs80338729, CM003063, COSV55711009; ClinVar: pathogenic; called by muse, mutect2
- STK11 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 71/190 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1060499964, COSV58820842, COSV58825712; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TCF4 | c.1829C>T p.A610V | Missense Mutation (SNP) | VAF 314/1005 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1568303352, CM091864, COSV61890423; ClinVar: pathogenic; called by muse, varscan2
- TLK2 | c.364C>T p.R122* | Nonsense Mutation (SNP) | VAF 176/574 reads (31%) | catalogued as rs1567870541, COSV58299985, COSV58306972; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 173/457 reads (38%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 153/431 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, varscan2
- TRPS1 | c.2854C>T p.R952C (on ENST00000220888 / NM_001330599.2; = p.R965C on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 499/1552 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs28939069, CM040268, COSV55228014; ClinVar: pathogenic; called by muse, mutect2, varscan2
- VPS13B | c.412+1G>A p.X138_splice | Splice Site (SNP) | VAF 50/826 reads (6%) | catalogued as rs1057517295, CS1512345; ClinVar: likely pathogenic; called by muse, mutect2
- ZBTB24 | c.958C>T p.R320* | Nonsense Mutation (SNP) | VAF 198/608 reads (33%) | catalogued as rs387907104, CM114080, COSV57781884; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2M | c.3322G>A p.A1108T | Missense Mutation (SNP) | VAF 122/864 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs746089621, COSV59387039; called by muse, mutect2, varscan2
- A4GALT | c.973C>T p.R325W | Missense Mutation (SNP) | VAF 105/306 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as rs767523802, COSV50743989; called by muse, mutect2, varscan2
- A4GALT | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 105/296 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as rs748424520, COSV50744243; called by muse, mutect2, varscan2
- AACS | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 121/357 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs775876225, COSV55536713; called by muse, mutect2, varscan2
- AARD | c.26G>A p.C9Y | Missense Mutation (SNP) | VAF 270/800 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.035); catalogued as COSV100991957, COSV65600563; called by muse, mutect2, varscan2
- AARS1 | c.2027C>T p.A676V | Missense Mutation (SNP) | VAF 133/407 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs371114066, COSV55749562; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AASDH | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 290/880 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs188668680, COSV52711592; called by muse, mutect2, varscan2
- AATK | c.1255C>T p.P419S (on ENST00000326724 / NM_001080395.3; = p.P316S on NM_004920.2) | Missense Mutation (SNP) | VAF 74/216 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1418841939; called by muse, varscan2
- ABCA1 | c.3634G>A p.A1212T | Missense Mutation (SNP) | VAF 309/848 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as COSV101037501; called by muse, mutect2, varscan2
- ABCA1 | c.2947G>A p.V983M | Missense Mutation (SNP) | VAF 302/906 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1191482801, COSV66065232; called by muse, mutect2, varscan2
- ABCA10 | c.4475C>T p.A1492V | Missense Mutation (SNP) | VAF 239/868 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.223); catalogued as rs765919520, COSV52217900; called by muse, mutect2, varscan2
- ABCA12 | c.3838G>A p.G1280S (on ENST00000272895 / NM_173076.3; = p.G962S on NM_015657.3) | Missense Mutation (SNP) | VAF 244/813 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775920671, COSV55972543, COSV99790120; called by muse, mutect2, varscan2
- ABCA13 | c.410G>T p.R137I | Missense Mutation (SNP) | VAF 292/951 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.156); catalogued as rs201247339, COSV101330000; called by muse, mutect2, varscan2
- ABCA13 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 366/1044 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.204); catalogued as rs769275074; called by muse, varscan2
- ABCA2 | c.6004G>A p.A2002T (on ENST00000614293; = p.A1972T on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 120/357 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.454); catalogued as rs764172707; called by muse, mutect2, varscan2
- ABCA4 | c.2878G>A p.A960T | Missense Mutation (SNP) | VAF 288/888 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.295); catalogued as rs772463435; called by muse, mutect2, varscan2
- ABCA5 | c.1812G>A p.M604I | Missense Mutation (SNP) | VAF 337/1125 reads (30%) | SIFT tolerated (0.92); PolyPhen possibly damaging (0.718); catalogued as rs988079817; called by muse, mutect2, varscan2
- ABCA5 | c.156G>A p.M52I | Missense Mutation (SNP) | VAF 152/570 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.051); catalogued as rs534436116; called by muse, mutect2, varscan2
- ABCA7 | c.1957G>A p.A653T | Missense Mutation (SNP) | VAF 54/138 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1210620933, COSV54024712; called by muse, mutect2, varscan2
- ABCA7 | c.4639T>C p.S1547P | Missense Mutation (SNP) | VAF 72/226 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs778244634; called by muse, mutect2, varscan2
- ABCA9 | c.4115C>T p.A1372V | Missense Mutation (SNP) | VAF 229/652 reads (35%) | SIFT tolerated (0.82); PolyPhen benign (0.01); catalogued as rs778683579, COSV60626018; called by muse, mutect2, varscan2
- ABCB10 | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 97/363 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs541827297; called by muse, mutect2, varscan2
- ABCB11 | c.1556G>A p.G519D | Missense Mutation (SNP) | VAF 631/1707 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55585698; called by muse, mutect2, varscan2
- ABCB4 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 294/859 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as rs1269792276, COSV55941342; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCB5 | c.584G>A p.G195D | Missense Mutation (SNP) | VAF 413/1398 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765461658, COSV99327770; called by muse, mutect2, varscan2
- ABCB5 | c.2197G>A p.E733K (on ENST00000404938 / NM_001163941.2; = p.E288K on NM_178559.6) | Missense Mutation (SNP) | VAF 329/985 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.287); catalogued as rs779350155, COSV99327801; called by muse, mutect2, varscan2
- ABCB6 | c.1316G>A p.R439H | Missense Mutation (SNP) | VAF 163/417 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775804124; called by muse, mutect2, varscan2
- ABCB9 | c.1738C>T p.R580C (on ENST00000280560 / NM_019625.4; = p.R537C on NM_019624.3) | Missense Mutation (SNP) | VAF 144/401 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as rs1286766702, COSV99757496; called by muse, mutect2, varscan2
- ABCC1 | c.3925G>A p.V1309I | Missense Mutation (SNP) | VAF 116/353 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.426); catalogued as rs759668292; called by muse, mutect2, varscan2
- ABCC10 | c.724C>T p.R242W (on ENST00000372530 / NM_001198934.2; = p.R199W on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/208 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as rs147197045; called by muse, mutect2, varscan2
- ABCC10 | c.3352C>T p.R1118W (on ENST00000372530 / NM_001198934.2; = p.R1090W on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 112/389 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773849977; called by muse, varscan2
- ABCC2 | c.1423C>T p.P475S | Missense Mutation (SNP) | VAF 258/778 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64988549; called by muse, mutect2, varscan2
- ABCC2 | c.2148G>T p.K716N | Missense Mutation (SNP) | VAF 300/902 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs1416560742, COSV64986381, COSV64988246; called by muse, mutect2, varscan2
- ABCC3 | c.1271C>T p.A424V | Missense Mutation (SNP) | VAF 53/337 reads (16%) | SIFT tolerated (0.96); PolyPhen benign (0.007); catalogued as rs1462288357; called by muse, mutect2, varscan2
- ABCC3 | c.2600C>T p.A867V | Missense Mutation (SNP) | VAF 153/517 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs760451698, COSV53321394; called by muse, mutect2, varscan2
- ABCC3 | c.4088G>A p.R1363H | Missense Mutation (SNP) | VAF 107/533 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370830587; called by muse, mutect2, varscan2
- ABCC6 | c.1459C>T p.R487W | Missense Mutation (SNP) | VAF 40/542 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374244303; called by muse, mutect2
- ABCC6 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 123/333 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.224); catalogued as rs776248626, COSV52742326; called by muse, mutect2, varscan2
- ABCD1 | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.069); catalogued as CD961754, COSV99497822; called by muse, mutect2
- ABCD1 | c.1660C>T p.R554C | Missense Mutation (SNP) | VAF 40/206 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.632); catalogued as rs398123104; called by muse, mutect2, varscan2
- ABCD4 | c.1171C>T p.R391W | Missense Mutation (SNP) | VAF 72/482 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs1318529059, COSV53990865; called by muse, mutect2, varscan2
- ABCG1 | c.1276C>T p.R426C | Missense Mutation (SNP) | VAF 182/553 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1304552863, COSV59202798; called by muse, mutect2, varscan2
- ABCG2 | c.1780G>T p.G594* | Nonsense Mutation (SNP) | VAF 460/1337 reads (34%) | catalogued as COSV99419598, COSV99420058; called by muse, mutect2, varscan2
- ABCG2 | c.764G>A p.S255N | Missense Mutation (SNP) | VAF 223/666 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.12); catalogued as rs892089260; called by muse, mutect2, varscan2
- ABCG4 | c.1352C>T p.A451V | Missense Mutation (SNP) | VAF 103/321 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.36); catalogued as rs754770221, COSV56646086; called by muse, mutect2, varscan2
- ABCG4 | c.1540G>A p.A514T | Missense Mutation (SNP) | VAF 180/445 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as rs1565817375; called by muse, mutect2, varscan2
- ABCG8 | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 116/330 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs764334802, COSV55393476; called by muse, mutect2, varscan2
- ABHD1 | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 126/354 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as rs780115059; called by muse, mutect2, varscan2
- ABHD10 | c.787C>T p.R263* | Nonsense Mutation (SNP) | VAF 412/1291 reads (32%) | catalogued as rs1381316613, COSV56324640; called by muse, varscan2
- ABHD16B | c.1163G>A p.R388H | Missense Mutation (SNP) | VAF 91/289 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1479500401; called by muse, mutect2, varscan2
- ABHD17A | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 90/378 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.132); catalogued as rs558746495, COSV51750593; called by muse, varscan2
- ABHD17C | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 275/847 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.327); catalogued as COSV51918012; called by muse, mutect2, varscan2
- ABHD18 | c.409C>T p.R137* (on ENST00000398965 / NM_001039717.2; = p.R10* on NM_025097.2 and 10 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 66/1072 reads (6%) | catalogued as rs1422365325, COSV66294741; called by muse, mutect2
- ABHD6 | c.532T>C p.Y178H | Missense Mutation (SNP) | VAF 114/348 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV55909225; called by muse, mutect2, varscan2
- ABI3BP | c.3110G>A p.R1037H | Missense Mutation (SNP) | VAF 458/1406 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778790101; called by muse, varscan2
- ABL1 | c.1700C>T p.A567V | Missense Mutation (SNP) | VAF 250/690 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs982716836; called by muse, mutect2, varscan2
- ABL1 | c.1702G>A p.V568M | Missense Mutation (SNP) | VAF 253/702 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.336); catalogued as rs141983052; called by muse, mutect2, varscan2
- ABL2 | c.2003G>A p.R668H (on ENST00000502732 / NM_007314.4; = p.R653H on NM_005158.5) | Missense Mutation (SNP) | VAF 122/330 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1367567317, COSV61013226; called by muse, mutect2, varscan2
- ABLIM1 | c.1388G>A p.R463H | Missense Mutation (SNP) | VAF 286/747 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as rs767288520, COSV99522348; called by muse, varscan2
- ABO | c.801dup p.F268Vfs*124 | Frame Shift Ins (INS) | VAF 104/396 reads (26%) | catalogued as rs782782485; called by mutect2, varscan2
- ABRA | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 193/561 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as rs1468720012; called by muse, mutect2, varscan2
- ABRAXAS2 | c.376G>A p.V126I | Missense Mutation (SNP) | VAF 286/981 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.068); catalogued as rs779280502, COSV53716757; called by muse, mutect2, varscan2
- ABT1 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 273/741 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV51292342; called by muse, mutect2, varscan2
- ABTB1 | c.1301C>T p.T434M (on ENST00000232744 / NM_172027.3; = p.T292M on NM_032548.3) | Missense Mutation (SNP) | VAF 155/435 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.496); catalogued as rs766497757, COSV51742967; called by muse, mutect2, varscan2
- AC005833.1 | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 285/821 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.125); catalogued as rs373419543, COSV52899928; called by muse, mutect2, varscan2
- AC006059.2 | c.1402C>T p.R468* | Nonsense Mutation (SNP) | VAF 161/451 reads (36%) | catalogued as rs564647857, COSV100045189; called by muse, varscan2
- AC008676.3 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 257/783 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs746011811; called by muse, mutect2, varscan2
- AC011462.1 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 67/251 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs753231061, COSV54195463; called by muse, mutect2, varscan2
- AC011462.1 | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 141/354 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs886042356; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AC011462.1 | c.1196G>A p.R399Q | Missense Mutation (SNP) | VAF 142/453 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.317); catalogued as rs375957868; called by muse, mutect2, varscan2
- AC013489.1 | c.943G>A p.A315T | Missense Mutation (SNP) | VAF 247/820 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.272); catalogued as rs762443912, COSV99183836; called by muse, mutect2, varscan2
- AC100868.1 | c.702T>C p.N234= | Splice Region (SNP) | VAF 301/804 reads (37%) | catalogued as rs754431963; called by muse, mutect2, varscan2
- AC109583.1 | c.1064A>G p.D355G | Missense Mutation (SNP) | VAF 128/308 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); catalogued as rs1046596238; called by muse, mutect2, varscan2
- AC109583.1 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 238/616 reads (39%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs749611912; called by muse, varscan2
- ACACB | c.5453G>A p.R1818Q | Missense Mutation (SNP) | VAF 214/602 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs151300416; called by muse, mutect2, varscan2
- ACAD11 | c.2053C>T p.R685C | Missense Mutation (SNP) | VAF 172/1028 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs578141275; called by muse, mutect2, varscan2
- ACAD11 | c.1819C>T p.R607* | Nonsense Mutation (SNP) | VAF 110/880 reads (13%) | catalogued as rs772764413, COSV99391621; called by muse, mutect2, varscan2
- ACADSB | c.260C>T p.S87L | Missense Mutation (SNP) | VAF 256/797 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.584); catalogued as rs745481903, COSV62551017; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACADSB | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 394/1127 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as rs1564754515; called by muse, varscan2
- ACADSB | c.1100C>T p.A367V | Missense Mutation (SNP) | VAF 358/1050 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs745900584, COSV62551468; called by muse, varscan2
- ACAN | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 143/422 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs760009352, COSV61363972; called by muse, mutect2, varscan2
- ACAP1 | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 112/328 reads (34%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs762483497, COSV50140089; called by muse, mutect2, varscan2
- ACAP2 | c.1703G>A p.S568N | Missense Mutation (SNP) | VAF 218/574 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.125); catalogued as rs768677851; called by muse, varscan2
- ACAP2 | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 44/832 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1251813082, COSV58755489; called by muse, mutect2
- ACAP3 | c.2290G>A p.A764T | Missense Mutation (SNP) | VAF 71/188 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.255); catalogued as rs905499709; called by muse, mutect2, varscan2
- ACAP3 | c.2095G>A p.A699T | Missense Mutation (SNP) | VAF 58/175 reads (33%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as rs368485636; called by muse, varscan2
- ACAP3 | c.193T>C p.S65P | Missense Mutation (SNP) | VAF 81/231 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs866715320; called by muse, mutect2, varscan2
- ACCS | c.877G>A p.V293M | Missense Mutation (SNP) | VAF 160/478 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs1053652280, COSV55458186, COSV55459706; called by muse, mutect2, varscan2
- ACKR2 | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 154/451 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs1478191949, COSV56178455; called by muse, mutect2, varscan2
- ACKR4 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 274/827 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs1421897777; called by muse, mutect2, varscan2
- ACLY | c.1067G>A p.G356D | Missense Mutation (SNP) | VAF 258/657 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as rs1555631680, COSV61252727; called by muse, mutect2, varscan2
- ACO1 | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 149/584 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs757411707, COSV100008298; called by muse, mutect2, varscan2
- ACO2 | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 28/340 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.71); catalogued as rs1389336695, COSV53440878; called by muse, mutect2
- ACO2 | c.694G>A p.V232M | Missense Mutation (SNP) | VAF 18/391 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.948); catalogued as rs1301732484, COSV53442012; called by muse, mutect2
- ACOT11 | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 183/487 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1176342736, COSV100650739; called by muse, mutect2, varscan2
- ACOX1 | c.871C>T p.R291W | Missense Mutation (SNP) | VAF 210/578 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs778134359, COSV53135303; ClinVar: uncertain significance; called by muse, varscan2
- ACOX1 | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 220/644 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs767721951, COSV53132259; called by muse, mutect2, varscan2
- ACOX3 | c.2093C>T p.S698L | Missense Mutation (SNP) | VAF 213/551 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.379); catalogued as rs762558027, COSV62711619; called by muse, mutect2, varscan2
- ACOX3 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 224/652 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs556118466; called by muse, mutect2, varscan2
- ACP2 | c.1043G>A p.R348H | Missense Mutation (SNP) | VAF 178/330 reads (54%) | SIFT tolerated (0.55); PolyPhen benign (0.196); catalogued as rs369127025; called by muse, mutect2, varscan2
- ACP2 | c.307C>T p.R103* | Nonsense Mutation (SNP) | VAF 153/516 reads (30%) | catalogued as rs765270069; called by muse, mutect2, varscan2
- ACP4 | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 66/202 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as rs1312501050; called by muse, mutect2, varscan2
- ACP6 | c.1240G>T p.A414S | Missense Mutation (SNP) | VAF 281/892 reads (32%) | SIFT tolerated (0.91); PolyPhen benign (0.01); catalogued as COSV65077762; called by muse, mutect2, varscan2
- ACP7 | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 109/329 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.086); catalogued as rs1352763634, COSV58698443; called by muse, varscan2
- ACSF2 | c.904C>T p.R302W | Missense Mutation (SNP) | VAF 171/492 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199781071; called by muse, mutect2, varscan2
- ACSF2 | c.1177C>T p.R393* | Nonsense Mutation (SNP) | VAF 202/580 reads (35%) | catalogued as rs146450795; called by muse, mutect2, varscan2
- ACSF2 | c.1680C>A p.D560E | Missense Mutation (SNP) | VAF 146/440 reads (33%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV51955018; called by mutect2, varscan2
- ACSF3 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 30/270 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs745633046, COSV58081288; called by muse, mutect2
- ACSL1 | c.1571C>T p.A524V | Missense Mutation (SNP) | VAF 230/676 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs200209968, COSV55661706; called by muse, mutect2, varscan2
- ACSL1 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 348/964 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs762658676, COSV55663671; called by muse, mutect2, varscan2
- ACSL6 | c.1624G>A p.G542R (on ENST00000379240; = p.G567R on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 199/640 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs543745359, COSV57305596; called by muse, mutect2, varscan2
- ACSM2A | c.585G>T p.K195N (on ENST00000219054; = p.K116N on NM_001308169.2) | Missense Mutation (SNP) | VAF 436/1337 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.058); catalogued as COSV99525485; called by muse, mutect2, varscan2
- ACSM3 | c.1387G>A p.G463R | Missense Mutation (SNP) | VAF 226/742 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1220065776; called by muse, varscan2
- ACSM5 | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 239/722 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141267278; called by muse, mutect2, varscan2
- ACSS1 | c.1429G>A p.V477I | Missense Mutation (SNP) | VAF 205/579 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as rs138608122; called by muse, mutect2, varscan2
- ACSS3 | c.2056G>A p.A686T | Missense Mutation (SNP) | VAF 374/1181 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV54084635; called by muse, varscan2
- ACTC1 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 330/916 reads (36%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.636); catalogued as COSV51758927, COSV51762255; called by muse, mutect2, varscan2
- ACTG2 | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 29/619 reads (5%) | catalogued as rs864309491, CM143761; called by muse, mutect2
- ACTL7A | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 186/606 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.974); catalogued as rs75408782; called by muse, varscan2
- ACTL7A | c.893C>T p.T298M | Missense Mutation (SNP) | VAF 228/682 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as rs753096025; called by muse, mutect2, varscan2
- ACTL7A | c.1256G>A p.R419H | Missense Mutation (SNP) | VAF 221/723 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs957486229, COSV100453269; called by muse, mutect2, varscan2
- ACTN1 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 293/830 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as rs368583570; called by muse, mutect2, varscan2
- ACTN2 | c.740C>T p.T247M | Missense Mutation (SNP) | VAF 316/974 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755492182, COSV100856819; ClinVar: uncertain significance; called by muse, varscan2
- ACTN2 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 152/499 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as COSV100857027; called by muse, mutect2, varscan2
- ACTN2 | c.2194G>A p.A732T | Missense Mutation (SNP) | VAF 319/905 reads (35%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.989); catalogued as rs777744290, COSV63978407; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTN4 | c.1639G>A p.A547T | Missense Mutation (SNP) | VAF 176/503 reads (35%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.538); catalogued as rs762475438, COSV99400248; called by muse, mutect2, varscan2
- ACTR1B | c.1019C>T p.T340I | Missense Mutation (SNP) | VAF 165/551 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1359892671; called by muse, mutect2
- ACTR1B | c.544C>T p.R182W | Missense Mutation (SNP) | VAF 147/415 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs143709977; called by muse, mutect2, varscan2
- ACTR3B | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 163/1092 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.254); catalogued as rs745707695; called by muse, mutect2, varscan2
- ACTR5 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 21/402 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.04); catalogued as rs1432945716; called by muse, mutect2
- ACTR8 | c.430C>T p.R144* | Nonsense Mutation (SNP) | VAF 186/619 reads (30%) | catalogued as rs772449859; called by muse, varscan2
- ACVR1B | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 83/462 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV57774618, COSV57775037; called by muse, mutect2, varscan2
- ADA2 | c.985G>A p.D329N (on ENST00000262607; = p.D88N on NM_177405.3) | Missense Mutation (SNP) | VAF 129/338 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs369716341; called by muse, mutect2, varscan2
- ADAD2 | c.482C>T p.A161V (on ENST00000315906 / NM_001145400.2; = p.A233V on NM_139174.4) | Missense Mutation (SNP) | VAF 210/581 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as rs577228328, COSV51893583; called by muse, mutect2, varscan2
- ADAM12 | c.2449C>T p.R817* | Nonsense Mutation (SNP) | VAF 316/1019 reads (31%) | catalogued as rs769115498, COSV64133210; called by muse, varscan2
- ADAM17 | c.2212C>T p.R738C | Missense Mutation (SNP) | VAF 348/1024 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); catalogued as rs370064783; called by muse, mutect2, varscan2
- ADAM17 | c.1418G>A p.R473H | Missense Mutation (SNP) | VAF 254/803 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.359); catalogued as rs368697823; called by muse, mutect2, varscan2
- ADAM19 | c.1816C>T p.R606W | Missense Mutation (SNP) | VAF 147/439 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs764203673, COSV57431395; called by muse, mutect2, varscan2
- ADAM28 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 410/1283 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.575); catalogued as COSV56105729; called by muse, mutect2, varscan2
- ADAM8 | c.1984C>A p.L662M | Missense Mutation (SNP) | VAF 181/424 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.373); catalogued as COSV69864983; called by muse, mutect2, varscan2
- ADAM9 | c.940G>T p.G314* | Nonsense Mutation (SNP) | VAF 244/580 reads (42%) | catalogued as COSV101166036; called by muse, mutect2, varscan2
- ADAMDEC1 | c.796G>A p.V266I | Missense Mutation (SNP) | VAF 276/861 reads (32%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.705); catalogued as rs1397675872; called by muse, mutect2, varscan2
- ADAMTS13 | c.1700C>T p.A567V | Missense Mutation (SNP) | VAF 76/220 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs782272645, COSV63020869; called by muse, mutect2, varscan2
- ADAMTS13 | c.3410G>A p.S1137N | Missense Mutation (SNP) | VAF 83/247 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1369423333; called by muse, mutect2, varscan2
- ADAMTS14 | c.517G>A p.G173R | Missense Mutation (SNP) | VAF 156/427 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1047684991, COSV64599846; called by muse, mutect2, varscan2
- ADAMTS15 | c.1942G>A p.V648I | Missense Mutation (SNP) | VAF 197/622 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs774915694, COSV54511044; called by muse, mutect2, varscan2
- ADAMTS18 | c.319G>T p.E107* | Nonsense Mutation (SNP) | VAF 476/1405 reads (34%) | catalogued as COSV51407139; called by muse, mutect2, varscan2
- ADAMTS20 | c.4446G>A p.W1482* | Nonsense Mutation (SNP) | VAF 352/896 reads (39%) | catalogued as COSV67131947; called by muse, mutect2, varscan2
- ADAMTS20 | c.3295C>T p.R1099* | Nonsense Mutation (SNP) | VAF 114/1636 reads (7%) | catalogued as rs757261794, COSV101166089; called by muse, mutect2
- ADAMTS7 | c.4352G>A p.R1451Q | Missense Mutation (SNP) | VAF 148/428 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as rs746270162; called by muse, varscan2
- ADAMTS7 | c.4339G>A p.A1447T | Missense Mutation (SNP) | VAF 126/394 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0.029); catalogued as rs772921044; called by muse, varscan2
- ADAMTS9 | c.2426G>A p.G809E | Missense Mutation (SNP) | VAF 375/1140 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55782944; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2272C>T p.R758C | Missense Mutation (SNP) | VAF 326/1017 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs554272440, COSV65891963; called by muse, mutect2, varscan2
- ADAP2 | c.974G>A p.R325H | Missense Mutation (SNP) | VAF 40/592 reads (7%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as rs956226574, COSV100437159; called by muse, mutect2
- ADAR | c.2314G>A p.V772I | Missense Mutation (SNP) | VAF 322/887 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763229776, COSV99425614; called by muse, mutect2, varscan2
- ADCY1 | c.3265G>A p.V1089M | Missense Mutation (SNP) | VAF 215/589 reads (37%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.069); catalogued as rs749731471; called by muse, mutect2, varscan2
- ADCY10 | c.3565C>T p.R1189W | Missense Mutation (SNP) | VAF 124/736 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs141732535; called by muse, mutect2, varscan2
- ADCY3 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 193/565 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.647); catalogued as rs574413132; called by muse, mutect2, varscan2
- ADCY5 | c.2351C>T p.P784L | Missense Mutation (SNP) | VAF 146/495 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as COSV59197780; called by muse, mutect2, varscan2
- ADCY5 | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 112/404 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as rs745702684, COSV71901345, COSV71901359; called by muse, mutect2, varscan2
- ADCY9 | c.2704G>A p.A902T | Missense Mutation (SNP) | VAF 145/435 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs147280539; called by muse, mutect2
- ADCY9 | c.1030G>A p.D344N | Missense Mutation (SNP) | VAF 146/445 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.723); catalogued as rs779690355, COSV53577400; called by muse, mutect2, varscan2
- ADD2 | c.1433G>A p.R478H | Missense Mutation (SNP) | VAF 402/1179 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs150426440; called by muse, mutect2, varscan2
- ADGRA1 | c.733G>A p.V245M | Missense Mutation (SNP) | VAF 106/405 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.166); catalogued as rs560858305; called by muse, mutect2, varscan2
- ADGRA2 | c.1069C>T p.R357C | Missense Mutation (SNP) | VAF 156/404 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs373198805; called by muse, mutect2, varscan2
- ADGRA2 | c.2657G>A p.R886Q | Missense Mutation (SNP) | VAF 180/489 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756095204, COSV55105542; called by muse, mutect2, varscan2
- ADGRA3 | c.3789del p.D1264Mfs*3 | Frame Shift Del (DEL) | VAF 390/1239 reads (31%) | catalogued as rs778863401; called by mutect2, pindel, varscan2
- ADGRA3 | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 383/1088 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99293741; called by muse, mutect2, varscan2
- ADGRB1 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 125/286 reads (44%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV60099983; called by muse, mutect2, varscan2
- ADGRB1 | c.212C>T p.T71M | Missense Mutation (SNP) | VAF 64/366 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs1051979380; called by muse, varscan2
- ADGRB2 | c.1700G>A p.R567H | Missense Mutation (SNP) | VAF 178/498 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1424298631, COSV57074338, COSV99926649; called by muse, varscan2
- ADGRB2 | c.1414C>T p.P472S | Missense Mutation (SNP) | VAF 210/571 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.177); catalogued as COSV99926904; called by muse, mutect2, varscan2
- ADGRB3 | c.940C>T p.R314* | Nonsense Mutation (SNP) | VAF 384/1162 reads (33%) | catalogued as rs752634970, COSV65397795; called by muse, varscan2
- ADGRB3 | c.3290C>T p.A1097V | Missense Mutation (SNP) | VAF 464/1312 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs749140448, COSV53234890, COSV53245698; called by muse, mutect2, varscan2
- ADGRE1 | c.1453G>A p.G485S | Missense Mutation (SNP) | VAF 188/538 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.194); catalogued as rs1387258218; called by muse, mutect2, varscan2
- ADGRE5 | c.2204C>T p.A735V (on ENST00000242786 / NM_078481.4; = p.A642V on NM_001784.5) | Missense Mutation (SNP) | VAF 103/305 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs780589696, COSV54391434; called by muse, mutect2, varscan2
- ADGRF1 | c.1207C>T p.R403W | Missense Mutation (SNP) | VAF 154/1421 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.332); catalogued as rs752105985; called by muse, mutect2, varscan2
- ADGRF4 | c.192G>T p.Q64H | Missense Mutation (SNP) | VAF 329/995 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as rs1252291509; called by muse, mutect2, varscan2
- ADGRG2 | c.2714C>T p.S905F (on ENST00000379869 / NM_001079858.3; = p.S902F on NM_005756.4) | Missense Mutation (SNP) | VAF 263/377 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61337415; called by muse, mutect2, varscan2
- ADGRG7 | c.2254C>T p.R752W | Missense Mutation (SNP) | VAF 412/1091 reads (38%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.522); catalogued as rs550809239; called by muse, varscan2
- ADGRL2 | c.931G>A p.A311T | Missense Mutation (SNP) | VAF 188/1702 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1003335830, COSV54655876; called by muse, mutect2, varscan2
- ADGRL3 | c.731C>T p.P244L (on ENST00000506720 / NM_001322402.2; = p.P176L on NM_015236.6) | Missense Mutation (SNP) | VAF 489/1389 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72267883, COSV72268912; called by muse, mutect2, varscan2
- ADGRL3 | c.1667C>T p.S556L (on ENST00000506720 / NM_001322402.2; = p.S488L on NM_015236.6) | Missense Mutation (SNP) | VAF 66/830 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs574618340, COSV72231044; called by muse, mutect2
- ADGRL4 | c.1414C>T p.L472F | Missense Mutation (SNP) | VAF 615/1809 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as rs1430793657, COSV100876448, COSV66059809; called by muse, mutect2, varscan2
- ADGRV1 | c.1292C>T p.A431V | Missense Mutation (SNP) | VAF 355/837 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs111723628, COSV67991326; ClinVar: likely benign; called by muse, mutect2, varscan2
- ADGRV1 | c.3955C>T p.R1319W | Missense Mutation (SNP) | VAF 454/1098 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372789540, COSV101316359, COSV67989114; called by muse, varscan2
- ADIPOR1 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 137/448 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1160334516; called by muse, mutect2, varscan2
- ADPRHL1 | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 118/333 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as rs377658823; called by muse, mutect2, varscan2
- ADPRM | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 305/951 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs769413233, COSV65754595; called by muse, mutect2, varscan2
- ADPRM | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 105/1386 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.627); catalogued as rs199523732; called by muse, mutect2
- ADRA1A | c.412G>A p.V138I | Missense Mutation (SNP) | VAF 98/899 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.812); catalogued as COSV52370947; called by muse, varscan2
- ADRA1D | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 54/384 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs763526391; called by muse, mutect2, varscan2
- ADRA2A | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 93/222 reads (42%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs1289034488; called by muse, mutect2, varscan2
- ADRA2B | c.1133G>A p.G378D | Missense Mutation (SNP) | VAF 130/359 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69787924; called by muse, mutect2, varscan2
- ADRA2B | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 58/323 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1262534626; called by muse, varscan2
- AEBP1 | c.1982G>T p.R661L | Missense Mutation (SNP) | VAF 154/497 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56257196; called by muse, mutect2, varscan2
- AEBP2 | c.200G>A p.G67D | Missense Mutation (SNP) | VAF 140/424 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as rs1056811830; called by muse, mutect2, varscan2
- AEN | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 94/298 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs752361817, COSV60429396; called by muse, mutect2, varscan2
- AFDN | c.3221C>T p.A1074V | Missense Mutation (SNP) | VAF 213/509 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1383117462, COSV100653072; called by muse, mutect2, varscan2
- AFDN | c.3821G>A p.R1274H | Missense Mutation (SNP) | VAF 383/973 reads (39%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); catalogued as rs774470994, COSV100652902; called by muse, mutect2, varscan2
- AFDN | c.4673G>A p.R1558H | Missense Mutation (SNP) | VAF 168/477 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as COSV60044148; called by muse, mutect2, varscan2
- AFDN | c.4906C>T p.R1636W (on ENST00000447894 / NM_001366320.1; = p.R1634W on NM_001040000.3) | Missense Mutation (SNP) | VAF 92/1484 reads (6%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs368769724, COSV100653912; called by muse, mutect2
- AFDN | c.5381G>A p.R1794H (on ENST00000447894 / NM_001366320.1; = p.R1713H on NM_001207008.1) | Missense Mutation (SNP) | VAF 414/1177 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1236738007, COSV63537733; called by muse, mutect2, varscan2
- AFF3 | c.1948C>T p.R650C | Missense Mutation (SNP) | VAF 125/328 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1476255226, COSV57865176; called by muse, mutect2, varscan2
- AFG3L2 | c.1079C>T p.A360V | Missense Mutation (SNP) | VAF 98/713 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52315945; called by muse, mutect2, varscan2
- AFP | c.26dup p.L9Ffs*9 | Frame Shift Ins (INS) | VAF 457/1240 reads (37%) | catalogued as rs1479715998; called by mutect2, varscan2
- AGAP1 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 165/554 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs779782500, COSV58325426; called by muse, mutect2, varscan2
- AGAP1 | c.2312C>T p.T771M (on ENST00000304032 / NM_001037131.3; = p.T718M on NM_014914.5) | Missense Mutation (SNP) | VAF 109/328 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs992108060; called by muse, mutect2, varscan2
- AGAP3 | c.598+7C>T | Splice Region (SNP) | VAF 41/330 reads (12%) | catalogued as rs1356477643; called by muse, mutect2, varscan2
- AGAP3 | c.1484G>A p.R495H (on ENST00000622464; = p.R531H on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 170/483 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.787); catalogued as rs753131439; called by muse, mutect2, varscan2
- AGAP9 | c.1898G>A p.R633H | Missense Mutation (SNP) | VAF 28/553 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.056); catalogued as rs1443829650; called by muse, mutect2
- AGBL5 | c.398C>T p.T133M | Missense Mutation (SNP) | VAF 181/548 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.927); catalogued as rs769641954, COSV59936065; called by muse, mutect2, varscan2
- AGFG2 | c.979G>A p.A327T | Missense Mutation (SNP) | VAF 123/364 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as rs778865607, COSV104368550; called by muse, mutect2, varscan2
- AGL | c.1874C>T p.T625M | Missense Mutation (SNP) | VAF 338/964 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs147569805, COSV54059039; ClinVar: uncertain significance; called by muse, varscan2
- AGL | c.4079G>A p.G1360D | Missense Mutation (SNP) | VAF 122/1453 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as rs1361507097; ClinVar: uncertain significance; called by muse, mutect2
- AGO4 | c.85C>T p.R29* | Nonsense Mutation (SNP) | VAF 259/749 reads (35%) | catalogued as COSV64617106; called by muse, mutect2, varscan2
- AGPAT3 | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 198/526 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1230314834, COSV52369592; called by muse, mutect2, varscan2
- AGRN | c.1323G>A p.W441* | Nonsense Mutation (SNP) | VAF 80/219 reads (37%) | catalogued as rs1557702487; called by muse, mutect2, varscan2
- AGRN | c.1654C>T p.R552C | Missense Mutation (SNP) | VAF 79/219 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs556149611; called by muse, varscan2
- AGRN | c.4512C>T p.A1504= | Splice Region (SNP) | VAF 72/208 reads (35%) | catalogued as rs759230236, COSV101039037; called by muse, varscan2
- AGRN | c.4855C>T p.R1619C | Missense Mutation (SNP) | VAF 136/351 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs767596151; called by muse, mutect2
- AGRN | c.5051C>T p.T1684M | Missense Mutation (SNP) | VAF 92/236 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs779378422; called by muse, mutect2, varscan2
- AGRN | c.5192G>A p.R1731Q | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs545570388; called by muse, mutect2, varscan2
- AGRN | c.5738C>T p.T1913M | Missense Mutation (SNP) | VAF 101/276 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.727); catalogued as rs201604787; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AGTPBP1 | c.812G>A p.G271E | Missense Mutation (SNP) | VAF 256/1627 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV61277180; called by muse, mutect2, varscan2
- AHCYL2 | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 243/721 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs772673247; called by muse, mutect2, varscan2
- AHDC1 | c.4237C>T p.R1413W | Missense Mutation (SNP) | VAF 80/208 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as rs777716141, COSV99899777; called by muse, mutect2, varscan2
- AHNAK | c.11770C>T p.R3924* | Nonsense Mutation (SNP) | VAF 135/1016 reads (13%) | catalogued as rs866059259, COSV57208909; called by muse, mutect2, varscan2
- AHNAK2 | c.13057G>A p.A4353T | Missense Mutation (SNP) | VAF 97/267 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.155); catalogued as rs375501382; called by muse, mutect2, varscan2
- AHNAK2 | c.7681G>A p.G2561S | Missense Mutation (SNP) | VAF 80/258 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.053); catalogued as rs372983447; called by muse, varscan2
- AHNAK2 | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 116/351 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as rs779111209, COSV100317705; called by muse, varscan2
- AHNAK2 | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 175/549 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753328136, COSV60913016; called by muse, mutect2, varscan2
- AHRR | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 28/656 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1366005071, COSV100327116; called by muse, mutect2
- AIDA | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 273/826 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.061); catalogued as rs376034063; called by muse, mutect2, varscan2
- AIM2 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 439/1235 reads (36%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs541126098; called by muse, mutect2, varscan2
- AK7 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 243/757 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs781727092, COSV50870814; called by muse, mutect2, varscan2
- AKAP12 | c.3535G>A p.D1179N | Missense Mutation (SNP) | VAF 206/557 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as rs747371302; called by muse, mutect2, varscan2
- AKAP13 | c.3358G>A p.V1120I | Missense Mutation (SNP) | VAF 173/490 reads (35%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.06); catalogued as rs757567881; called by muse, mutect2, varscan2
- AKAP17A | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 131/374 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.165); catalogued as rs761817742; called by muse, mutect2, varscan2
- AKNA | c.3944C>T p.A1315V | Missense Mutation (SNP) | VAF 74/443 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs752206512, COSV56334854; called by muse, mutect2, varscan2
- AKR1B1 | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 267/834 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.731); catalogued as rs770279911, COSV53648323; called by muse, mutect2, varscan2
- AKR1B1 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 65/955 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as rs1229108905, COSV53646458; called by muse, mutect2
- AKR1B15 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 281/959 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.667); catalogued as rs201762103; called by muse, mutect2, varscan2
- AKT1 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 60/343 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs756697784; called by muse, mutect2, varscan2
- AKT2 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 69/444 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.146); catalogued as rs746407532; called by muse, mutect2, varscan2
- AKTIP | c.43C>T p.R15* | Nonsense Mutation (SNP) | VAF 126/386 reads (33%) | catalogued as COSV55815286; called by muse, mutect2, varscan2
- AL133304.2 | n.202C>T | Splice Region (SNP) | VAF 404/1190 reads (34%) | catalogued as rs756731689; called by muse, mutect2, varscan2
- AL358113.1 | c.3913C>T p.R1305C | Missense Mutation (SNP) | VAF 212/612 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as rs764463413, COSV61958730; called by muse, mutect2, varscan2
- AL592490.1 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 292/904 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.86); catalogued as COSV69425230, COSV69428005; called by muse, varscan2
- ALDH16A1 | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 82/247 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1184857655; called by muse, mutect2, varscan2
- ALDH16A1 | c.2372C>T p.A791V | Missense Mutation (SNP) | VAF 105/301 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.167); catalogued as rs754754057; called by muse, mutect2, varscan2
- ALDH1A2 | c.1241C>T p.A414V | Missense Mutation (SNP) | VAF 408/1193 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51082060; called by muse, mutect2, varscan2
- ALDH1B1 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 101/264 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as rs775731660, COSV66619652, COSV66619678; called by muse, varscan2
- ALDH1L1 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 62/676 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs370724859; called by muse, mutect2
- ALDH1L2 | c.995C>T p.T332M | Missense Mutation (SNP) | VAF 286/862 reads (33%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.06); catalogued as rs138795159; called by muse, mutect2, varscan2
- ALDH3A1 | c.1226G>A p.G409D | Missense Mutation (SNP) | VAF 170/454 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1290799144; called by muse, varscan2
- ALDH3A1 | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 147/463 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs756253107, COSV56736651; called by muse, mutect2, varscan2
- ALDH3B2 | c.374C>A p.P125H | Missense Mutation (SNP) | VAF 107/294 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62429251; called by muse, mutect2, varscan2
- ALDH5A1 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 68/211 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs1480831485; called by muse, varscan2
- ALDH5A1 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 237/765 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs773814880, COSV62373402, COSV62374578; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALDOC | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 224/661 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.415); catalogued as rs765845189, COSV52024310; called by muse, mutect2, varscan2
- ALG1 | c.1120G>A p.D374N | Missense Mutation (SNP) | VAF 168/635 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1481213667; called by muse, mutect2
- ALG10B | c.835C>T p.R279W | Missense Mutation (SNP) | VAF 756/2177 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1045176953, COSV100439956; called by muse, mutect2, varscan2
- ALG12 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 90/243 reads (37%) | PolyPhen benign (0.015); catalogued as rs578038511, COSV58206720; called by muse, mutect2, varscan2
- ALG5 | c.289C>T p.R97* | Nonsense Mutation (SNP) | VAF 362/1119 reads (32%) | catalogued as rs747848311, COSV99523651; called by muse, mutect2, varscan2
- ALKBH1 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 170/558 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.341); catalogued as COSV99380412; called by muse, mutect2
- ALKBH1 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 148/417 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138190342; called by muse, mutect2, varscan2
- ALKBH3 | c.397A>G p.T133A | Missense Mutation (SNP) | VAF 208/631 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs944525950; called by muse, mutect2, varscan2
- ALMS1 | c.3899C>T p.S1300L | Missense Mutation (SNP) | VAF 433/1277 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.057); catalogued as rs769219669, CM155362; called by muse, mutect2, varscan2
- ALOX12B | c.1303G>A p.V435I | Missense Mutation (SNP) | VAF 121/374 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs369807670; called by muse, mutect2, varscan2
- ALOX12B | c.37G>A p.D13N | Missense Mutation (SNP) | VAF 151/420 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.046); catalogued as rs775449310, COSV59872873; called by muse, varscan2
- ALPI | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 218/589 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as rs148557980; called by muse, varscan2
- ALPI | c.970G>A p.G324S | Missense Mutation (SNP) | VAF 94/517 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1477155721; called by muse, varscan2
- ALPK3 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 83/488 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as rs762887736, COSV51935540; called by muse, mutect2, varscan2
- ALPK3 | c.3037C>T p.R1013C | Missense Mutation (SNP) | VAF 83/323 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs142109538; called by muse, mutect2, varscan2
- ALS2 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 299/856 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.553); catalogued as rs576502295; called by muse, mutect2, varscan2
- AMDHD1 | c.17G>A p.S6N | Missense Mutation (SNP) | VAF 140/630 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1427756850; called by muse, mutect2, varscan2
- AMER2 | c.1733C>T p.T578M | Missense Mutation (SNP) | VAF 208/633 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.621); catalogued as rs150090375; called by muse, mutect2, varscan2
- AMFR | c.1762G>A p.E588K | Missense Mutation (SNP) | VAF 61/827 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as rs779952471, COSV51922629; called by muse, mutect2
- AMH | c.1388C>T p.A463V | Missense Mutation (SNP) | VAF 94/233 reads (40%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.881); catalogued as rs146124583; called by muse, mutect2, varscan2
- AMHR2 | c.800dup p.P268Sfs*30 | Frame Shift Ins (INS) | VAF 57/336 reads (17%) | catalogued as rs748387033; called by mutect2, varscan2
- AMPD1 | c.2281C>T p.R761C | Missense Mutation (SNP) | VAF 370/1076 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777802711, COSV100815164, COSV62416295; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AMPD1 | c.1391G>A p.R464H | Missense Mutation (SNP) | VAF 302/864 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs61757695; called by muse, mutect2, varscan2
- AMPD2 | c.574C>T p.R192W | Missense Mutation (SNP) | VAF 78/463 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs762910071, COSV99857697; called by muse, mutect2, varscan2
- AMPD2 | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 160/474 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as rs935098442, COSV99857744; called by muse, varscan2
- AMTN | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 179/774 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV100219672, COSV59489048; called by muse, mutect2, varscan2
- ANAPC1 | c.4664A>G p.H1555R | Missense Mutation (SNP) | VAF 224/851 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as rs1238501675; called by muse, mutect2, varscan2
- ANAPC1 | c.592G>A p.V198I | Missense Mutation (SNP) | VAF 287/806 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.237); catalogued as rs971546753; called by muse, mutect2, varscan2
- ANAPC2 | c.1741C>T p.R581W | Missense Mutation (SNP) | VAF 111/368 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.155); catalogued as COSV60570618; called by muse, mutect2, varscan2
- ANAPC5 | c.1405G>A p.A469T | Missense Mutation (SNP) | VAF 110/372 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.295); catalogued as rs1028125388, COSV55844670; called by muse, mutect2, varscan2
- ANGPT2 | c.700del p.I234* | Frame Shift Del (DEL) | VAF 304/908 reads (33%) | catalogued as rs34047276; called by mutect2, varscan2
- ANGPT4 | c.1442G>T p.W481L | Missense Mutation (SNP) | VAF 160/534 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1202147803; called by mutect2, varscan2
- ANGPTL6 | c.1208G>A p.R403Q | Missense Mutation (SNP) | VAF 36/208 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.639); catalogued as rs1055750184; called by muse, varscan2
- ANGPTL8 | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 90/216 reads (42%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs749820131; called by muse, mutect2, varscan2
- ANHX | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 170/532 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as rs762774820; called by muse, mutect2, varscan2
- ANK1 | c.1891G>A p.E631K | Missense Mutation (SNP) | VAF 149/414 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as CM032177, COSV55885886; called by muse, varscan2
- ANK2 | c.2683C>T p.R895* | Nonsense Mutation (SNP) | VAF 330/916 reads (36%) | catalogued as CM124411; called by muse, mutect2, varscan2
- ANK2 | c.2684G>A p.R895Q | Missense Mutation (SNP) | VAF 297/900 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); catalogued as rs751513548, COSV52156051; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK2 | c.4740C>A p.S1580R | Missense Mutation (SNP) | VAF 383/2007 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1380887769; called by muse, mutect2, varscan2
- ANK3 | c.12367C>T p.R4123C (on ENST00000280772 / NM_001320874.2; = p.R644C on NM_001149.3) | Missense Mutation (SNP) | VAF 324/877 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs746915601; called by muse, mutect2, varscan2
- ANKDD1A | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 181/491 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.207); catalogued as rs377565868; called by muse, mutect2, varscan2
- ANKEF1 | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 473/1367 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.11); catalogued as rs528690112, COSV65692046; called by muse, mutect2, varscan2
- ANKFY1 | c.3151G>A p.A1051T (on ENST00000341657 / NM_001330063.2; = p.A1052T on NM_016376.5) | Missense Mutation (SNP) | VAF 204/614 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs865832436; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3961C>T p.R1321C | Missense Mutation (SNP) | VAF 166/508 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs1203872856, COSV51839681, COSV99782346; called by muse, mutect2, varscan2
- ANKIB1 | c.1973G>A p.R658H | Missense Mutation (SNP) | VAF 184/1326 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as rs369666134; called by muse, mutect2, varscan2
- ANKK1 | c.2201G>A p.R734H | Missense Mutation (SNP) | VAF 292/772 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs749107081; called by muse, mutect2, varscan2
- ANKLE2 | c.2020T>C p.C674R | Missense Mutation (SNP) | VAF 58/362 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs865795640; called by muse, varscan2
- ANKLE2 | c.1934A>G p.D645G | Missense Mutation (SNP) | VAF 159/453 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV100513972; called by muse, varscan2
- ANKMY1 | c.2438C>T p.A813V | Missense Mutation (SNP) | VAF 197/555 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as rs754606768, COSV56039730; called by muse, mutect2, varscan2
- ANKMY2 | c.199C>T p.R67* | Nonsense Mutation (SNP) | VAF 375/1094 reads (34%) | catalogued as rs1478992649; called by muse, mutect2, varscan2
- ANKRD10 | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 197/549 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs758425043, COSV57444968; called by muse, mutect2, varscan2
- ANKRD11 | c.7163G>A p.R2388H | Missense Mutation (SNP) | VAF 53/201 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV56358957; called by muse, mutect2, varscan2
- ANKRD11 | c.6049G>A p.A2017T | Missense Mutation (SNP) | VAF 121/334 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs1455558820, COSV56365024, COSV99969208; called by muse, varscan2
- ANKRD11 | c.5764G>A p.A1922T | Missense Mutation (SNP) | VAF 84/247 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as rs747284349; called by muse, mutect2, varscan2
- ANKRD11 | c.1295C>T p.T432M | Missense Mutation (SNP) | VAF 158/498 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs148472572; called by muse, mutect2, varscan2
- ANKRD13B | c.1312G>A p.G438S | Missense Mutation (SNP) | VAF 221/664 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.899); catalogued as rs745521454; called by muse, mutect2, varscan2
- ANKRD13B | c.1816C>T p.R606W | Missense Mutation (SNP) | VAF 121/312 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs1236284432, COSV61471760; called by muse, varscan2
- ANKRD16 | c.536-1G>A p.X179_splice | Splice Site (SNP) | VAF 119/405 reads (29%) | catalogued as rs1220586716; called by muse, mutect2, varscan2
- ANKRD18A | c.2744C>T p.S915L | Missense Mutation (SNP) | VAF 200/574 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs866752033, COSV57632718; called by muse, mutect2, varscan2
- ANKRD18B | c.1906_1908del p.E636del | In Frame Del (DEL) | VAF 222/728 reads (30%) | catalogued as rs1563904626; called by pindel, varscan2
- ANKRD23 | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 81/381 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.946); catalogued as rs1464953007; called by muse, mutect2, varscan2
- ANKRD24 | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 64/214 reads (30%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs1055419943; called by muse, mutect2, varscan2
- ANKRD27 | c.2600C>T p.A867V | Missense Mutation (SNP) | VAF 188/442 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753864994; called by muse, mutect2, varscan2
- ANKRD27 | c.2251G>A p.A751T | Missense Mutation (SNP) | VAF 68/210 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs751751587; called by muse, mutect2, varscan2
- ANKRD27 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 144/444 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs568458804, COSV60133721; called by muse, mutect2, varscan2
- ANKRD30A | c.1122G>A p.W374* (on ENST00000611781; = p.W318* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 504/1525 reads (33%) | catalogued as COSV100654496, COSV64614796; called by muse, varscan2
- ANKRD40CL | c.298C>T p.R100* (on ENST00000643007; = p.R72* on NM_001358683.3) | Nonsense Mutation (SNP) | VAF 156/488 reads (32%) | catalogued as rs898228461; called by muse, mutect2, varscan2
- ANKRD46 | c.-26C>T | Splice Region (SNP) | VAF 243/796 reads (31%) | catalogued as rs1225404228, COSV100169918; called by muse, mutect2, varscan2
- ANKRD52 | c.2675G>A p.R892H | Missense Mutation (SNP) | VAF 190/526 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.298); catalogued as rs201659742; called by muse, varscan2
- ANKRD52 | c.2159G>A p.R720Q | Missense Mutation (SNP) | VAF 116/395 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs750706398; called by muse, mutect2, varscan2
- ANKRD52 | c.1456G>A p.D486N | Missense Mutation (SNP) | VAF 37/656 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1368235699, COSV57285494; called by muse, mutect2
- ANKRD54 | c.719A>G p.Q240R | Missense Mutation (SNP) | VAF 89/223 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.616); catalogued as COSV99316388; called by muse, mutect2, varscan2
- ANKRD55 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 252/854 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs751710930; called by muse, mutect2, varscan2
- ANKRD61 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 180/478 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs780537670; called by muse, varscan2
- ANKRD61 | c.710C>T p.T237M | Missense Mutation (SNP) | VAF 180/528 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1404833507; called by muse, mutect2, varscan2
- ANKRD62 | c.512G>A p.G171E | Missense Mutation (SNP) | VAF 92/609 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV58412091; called by muse, mutect2, varscan2
- ANKRD65 | c.1039C>T p.H347Y | Missense Mutation (SNP) | VAF 93/269 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101408915; called by muse, mutect2, varscan2
- ANKS1A | c.322G>A p.V108M | Missense Mutation (SNP) | VAF 236/686 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.356); catalogued as rs138862271; called by muse, mutect2, varscan2
- ANKS1A | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 161/472 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1278638495; called by muse, varscan2
- ANKS3 | c.1465G>A p.A489T | Missense Mutation (SNP) | VAF 150/464 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.14); catalogued as rs961056150, COSV58508946; called by muse, mutect2, varscan2
- ANKS6 | c.1766C>T p.A589V | Missense Mutation (SNP) | VAF 162/522 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs368165175; called by muse, mutect2, varscan2
- ANKZF1 | c.1990C>T p.R664C | Missense Mutation (SNP) | VAF 159/500 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); catalogued as rs763770421; called by muse, mutect2, varscan2
- ANO1 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 162/500 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs1461039392; called by muse, mutect2, varscan2
- ANO2 | c.631G>A p.E211K (on ENST00000356134 / NM_001278597.3; = p.E215K on NM_001278596.3) | Missense Mutation (SNP) | VAF 177/537 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.209); catalogued as rs757415742, COSV59042871; called by muse, mutect2, varscan2
- ANO4 | c.1405C>T p.R469* (on ENST00000392977 / NM_001286615.2; = p.R434* on NM_178826.4) | Nonsense Mutation (SNP) | VAF 212/688 reads (31%) | catalogued as rs775993661, COSV100151219; called by muse, mutect2, varscan2
- ANO5 | c.1877A>G p.N626S | Missense Mutation (SNP) | VAF 178/557 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV61081754; called by muse, mutect2, varscan2
- ANO6 | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 489/1514 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775289465; called by muse, mutect2, varscan2
- ANO7 | c.1006C>T p.R336C (on ENST00000274979; = p.R282C on NM_001370694.2) | Missense Mutation (SNP) | VAF 112/339 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.48); catalogued as rs369123528; called by muse, mutect2, varscan2
- ANO9 | c.1268G>A p.R423H | Missense Mutation (SNP) | VAF 62/199 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs199668517, COSV100241263; called by muse, mutect2, varscan2
- ANTXR1 | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 328/879 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.164); catalogued as rs119475040, CM087499; ClinVar: risk factor; called by muse, mutect2, varscan2
- ANXA1 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 486/1449 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144842081; called by muse, mutect2, varscan2
- ANXA11 | c.941A>G p.Y314C | Missense Mutation (SNP) | VAF 98/290 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs758861889; called by muse, mutect2, varscan2
- ANXA2 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 251/693 reads (36%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.933); catalogued as rs747214524; called by muse, mutect2, varscan2
- ANXA6 | c.1577C>T p.A526V | Missense Mutation (SNP) | VAF 193/651 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs775326203; called by muse, mutect2, varscan2
- ANXA9 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 137/482 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760717286, COSV64484714; called by muse, mutect2, varscan2
- AOPEP | c.1513G>A p.A505T | Missense Mutation (SNP) | VAF 268/789 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs960335746; called by muse, mutect2, varscan2
- AOPEP | c.2180G>A p.R727Q (on ENST00000375315 / NM_001193329.1; = p.R628Q on NM_032823.5) | Missense Mutation (SNP) | VAF 399/1123 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs963224133, COSV52987575; called by muse, mutect2, varscan2
- AOX1 | c.2041G>A p.D681N | Missense Mutation (SNP) | VAF 276/823 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.12); catalogued as rs369839297; called by muse, mutect2, varscan2
- AOX1 | c.2761C>T p.R921C | Missense Mutation (SNP) | VAF 344/938 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866567689; called by muse, mutect2, varscan2
- AP000812.4 | c.154C>T p.R52W | Missense Mutation (SNP) | VAF 42/588 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.513); catalogued as rs1372399805, COSV99597694; called by muse, mutect2
- AP002748.5 | c.697C>T p.R233W | Missense Mutation (SNP) | VAF 100/304 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377159794; called by muse, mutect2, varscan2
- AP1AR | c.367C>T p.R123* | Nonsense Mutation (SNP) | VAF 261/842 reads (31%) | catalogued as rs1306100668; called by muse, mutect2, varscan2
- AP1B1 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 124/281 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756047868; called by muse, mutect2, varscan2
- AP1G1 | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 179/550 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs201798143, COSV55489581; called by muse, varscan2
- AP1M1 | c.163dup p.V55Gfs*32 | Frame Shift Ins (INS) | VAF 120/360 reads (33%) | catalogued as rs753324780; called by mutect2, varscan2
- AP1M2 | c.1129G>A p.G377R | Missense Mutation (SNP) | VAF 55/170 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs1202522150, COSV51566479, COSV51568642, COSV99140743; called by muse, mutect2, varscan2
- AP2A2 | c.1303G>A p.A435T | Missense Mutation (SNP) | VAF 187/512 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV59959873; called by muse, mutect2, varscan2
- AP2A2 | c.1774G>A p.D592N | Missense Mutation (SNP) | VAF 10/217 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as rs1312186255; called by muse, mutect2
- AP3B1 | c.1021C>T p.R341C | Missense Mutation (SNP) | VAF 84/1402 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs964935640, COSV99079483; called by muse, mutect2
- AP3D1 | c.2305G>A p.A769T | Missense Mutation (SNP) | VAF 130/326 reads (40%) | SIFT tolerated (0.48); PolyPhen benign (0.061); catalogued as rs557684269, COSV61425446; called by muse, mutect2, varscan2
- AP3S1 | c.458G>A p.G153D | Missense Mutation (SNP) | VAF 294/1074 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.774); catalogued as COSV57474905, COSV57476919; called by muse, varscan2
- AP4B1 | c.826C>T p.R276W | Missense Mutation (SNP) | VAF 169/536 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs758248128, COSV56724446; called by muse, mutect2, varscan2
- AP4E1 | c.133G>T p.A45S | Missense Mutation (SNP) | VAF 98/272 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs151135245; called by muse, mutect2, varscan2
- AP4M1 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 98/278 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as rs1248425173; called by muse, mutect2, varscan2
- AP5B1 | c.2086C>T p.R696C | Missense Mutation (SNP) | VAF 31/222 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as rs762220636; called by muse, mutect2, varscan2
- AP5S1 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 45/342 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1376813086; called by muse, varscan2
- AP5S1 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 108/322 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as rs776927558; called by muse, varscan2
- APBA2 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 93/261 reads (36%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs371759617; called by muse, mutect2, varscan2
- APBA3 | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 77/248 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1380985242; called by muse, mutect2, varscan2
- APBB1 | c.1402G>A p.V468I | Missense Mutation (SNP) | VAF 88/249 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as rs1394180630; called by muse, mutect2, varscan2
- APBB1 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 156/397 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as rs766381978, COSV54975389; called by muse, mutect2, varscan2
- APC2 | c.1834G>A p.A612T | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs752007377, COSV52016983; called by muse, mutect2, varscan2
- APC2 | c.2065G>A p.A689T | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as rs1314336949; called by muse, mutect2, varscan2
- APC2 | c.2758G>A p.A920T | Missense Mutation (SNP) | VAF 36/171 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756217331; called by muse, mutect2, varscan2
- APC2 | c.6380G>A p.R2127H | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.108); catalogued as rs1225837704; called by muse, varscan2
- API5 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 420/1100 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs543630471, COSV101124531; called by muse, mutect2, varscan2
- APLNR | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 195/510 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs764929700, COSV99951442; called by muse, mutect2, varscan2
- APLNR | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 166/494 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746176980, COSV57241783; called by muse, mutect2, varscan2
- APLP1 | c.1179G>T p.E393D | Missense Mutation (SNP) | VAF 116/356 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.654); catalogued as COSV55705532; called by muse, varscan2
- APLP1 | c.1217C>T p.A406V | Missense Mutation (SNP) | VAF 50/146 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.084); catalogued as rs368817415; called by muse, varscan2
- APLP1 | c.1256C>T p.A419V | Missense Mutation (SNP) | VAF 86/210 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.439); catalogued as rs1330917042, COSV99697950; called by muse, varscan2
- APLP2 | c.402C>T p.L134= | Splice Region (SNP) | VAF 192/569 reads (34%) | catalogued as rs150028786; called by muse, mutect2, varscan2
- APMAP | c.1072G>A p.V358M | Missense Mutation (SNP) | VAF 206/582 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.103); catalogued as rs767278761; called by muse, mutect2, varscan2
- APOE | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1426426514, CM014159; called by muse, mutect2, varscan2
- APOL2 | c.400G>A p.G134S | Missense Mutation (SNP) | VAF 303/789 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.666); catalogued as rs1464097849, COSV50772712; called by muse, mutect2, varscan2
- APOL5 | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 116/290 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1299564048; called by muse, mutect2, varscan2
- APPL2 | c.685G>A p.V229I | Missense Mutation (SNP) | VAF 48/806 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs1297444615; called by muse, mutect2
- AQP5 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 215/548 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs775341539; called by muse, mutect2, varscan2
- AQP7 | c.694C>T p.P232S | Missense Mutation (SNP) | VAF 107/356 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.089); catalogued as COSV53010995; called by muse, mutect2, varscan2
- ARAP1 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 67/215 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs532055299, COSV61991389; called by muse, varscan2
- ARAP3 | c.143G>A p.G48D | Missense Mutation (SNP) | VAF 98/253 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1393330228; called by muse, mutect2, varscan2
- AREG | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 479/1355 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as COSV99144397; called by muse, mutect2, varscan2
- ARFGEF2 | c.3035G>A p.R1012H | Missense Mutation (SNP) | VAF 281/904 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as rs780594033, COSV64215032; called by muse, mutect2, varscan2
- ARFGEF3 | c.2057G>A p.R686Q | Missense Mutation (SNP) | VAF 50/600 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs371564929; called by muse, mutect2
- ARFGEF3 | c.3784C>T p.R1262C | Missense Mutation (SNP) | VAF 304/879 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs770178501, COSV99292015; called by muse, mutect2, varscan2
- ARFIP2 | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 238/683 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs771258941, COSV99601442; called by muse, mutect2, varscan2
- ARHGAP10 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 60/786 reads (8%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.836); catalogued as COSV60598492, COSV60598845; called by muse, mutect2
- ARHGAP11B | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 98/1460 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.643); catalogued as rs748018819; called by muse, mutect2
- ARHGAP15 | c.1346C>T p.A449V | Missense Mutation (SNP) | VAF 516/1517 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.47); catalogued as rs748925321; called by muse, mutect2, varscan2
- ARHGAP19 | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 180/486 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1468117616; called by muse, mutect2, varscan2
- ARHGAP22 | c.1985C>T p.A662V | Missense Mutation (SNP) | VAF 298/938 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs769390603, COSV50948490; called by muse, mutect2, varscan2
- ARHGAP22 | c.1304C>T p.P435L | Missense Mutation (SNP) | VAF 139/358 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as rs763527109; called by muse, mutect2, varscan2
- ARHGAP22 | c.706C>T p.R236W | Missense Mutation (SNP) | VAF 141/355 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770347078; called by muse, mutect2, varscan2
- ARHGAP23 | c.2051C>T p.A684V | Missense Mutation (SNP) | VAF 176/489 reads (36%) | SIFT tolerated (0.76); PolyPhen benign (0.018); catalogued as rs750856610; called by muse, mutect2, varscan2
- ARHGAP23 | c.4192C>T p.R1398W | Missense Mutation (SNP) | VAF 68/162 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs1393189211; called by muse, mutect2, varscan2
- ARHGAP27 | c.2032C>T p.R678W (on ENST00000428638 / NM_001282290.1; = p.R337W on NM_199282.3) | Missense Mutation (SNP) | VAF 93/304 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs1052385323; called by muse, mutect2, varscan2
- ARHGAP29 | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 412/1288 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV53110295, COSV99558207; called by muse, mutect2, varscan2
- ARHGAP31 | c.1005G>A p.S335= | Splice Region (SNP) | VAF 234/839 reads (28%) | catalogued as rs764336285; called by muse, mutect2, varscan2
- ARHGAP33 | c.10C>T p.R4C | Missense Mutation (SNP) | VAF 63/188 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs757351355; called by muse, mutect2, varscan2
- ARHGAP33 | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 113/345 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs373692589, COSV50131638; called by muse, mutect2, varscan2
- ARHGAP33 | c.2467C>T p.R823W | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.019); catalogued as rs1465955933; called by muse, mutect2, varscan2
- ARHGAP39 | c.1664C>T p.A555V | Missense Mutation (SNP) | VAF 88/246 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.148); catalogued as COSV52773253; called by muse, mutect2, varscan2
- ARHGAP4 | c.1474C>T p.R492C | Missense Mutation (SNP) | VAF 212/308 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs782349092, COSV63131139; called by muse, mutect2, varscan2
- ARHGAP45 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 56/193 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.638); catalogued as rs1345112721; called by muse, mutect2, varscan2
- ARHGAP6 | c.75G>T p.K25N | Missense Mutation (SNP) | VAF 197/283 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.637); catalogued as COSV61636480; called by muse, mutect2, varscan2
- ARHGEF1 | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 83/233 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as rs782110668, COSV61526536; called by muse, mutect2, varscan2
- ARHGEF1 | c.497C>T p.T166M | Missense Mutation (SNP) | VAF 69/197 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1276987407; called by muse, mutect2, varscan2
- ARHGEF10L | c.1150G>A p.V384M | Missense Mutation (SNP) | VAF 193/550 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.627); catalogued as rs773305597; called by muse, mutect2, varscan2
- ARHGEF12 | c.1546C>T p.R516W | Missense Mutation (SNP) | VAF 60/946 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs748791499; called by muse, mutect2
- ARHGEF17 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 83/224 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.451); catalogued as rs1483234337; called by muse, mutect2, varscan2
- ARHGEF19 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 133/354 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as rs1245258685; called by muse, mutect2, varscan2
- ARHGEF2 | c.1627G>A p.A543T (on ENST00000361247 / NM_001162383.2; = p.A515T on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 134/421 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.086); catalogued as rs774997193; called by muse, mutect2, varscan2
- ARHGEF2 | c.1199G>A p.R400H (on ENST00000361247 / NM_001162383.2; = p.R372H on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 142/410 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1475947036, COSV58106020; called by muse, mutect2, varscan2
- ARHGEF28 | c.2962C>T p.R988* | Nonsense Mutation (SNP) | VAF 364/1360 reads (27%) | catalogued as rs946786357, COSV99708348; called by muse, mutect2, varscan2
- ARHGEF33 | c.1286G>A p.R429H | Missense Mutation (SNP) | VAF 301/917 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV104433150; called by muse, mutect2, varscan2
- ARHGEF4 | c.1556G>A p.R519Q | Missense Mutation (SNP) | VAF 209/602 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs536731766, COSV100387403; called by muse, mutect2, varscan2
- ARHGEF40 | c.3427C>T p.R1143W | Missense Mutation (SNP) | VAF 120/364 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs756140150; called by muse, varscan2
- ARHGEF40 | c.3461G>A p.R1154H | Missense Mutation (SNP) | VAF 112/324 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs780020334; called by muse, varscan2
- ARHGEF5 | c.3571C>T p.R1191C | Missense Mutation (SNP) | VAF 204/2095 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs560154773, COSV50209634; called by muse, mutect2, varscan2
- ARID4A | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 280/909 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368715644; called by muse, mutect2, varscan2
- ARID5A | c.757G>A p.G253S | Missense Mutation (SNP) | VAF 117/324 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs771274715; called by muse, mutect2, varscan2
- ARID5B | c.1922C>T p.A641V | Missense Mutation (SNP) | VAF 220/706 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs772420176, COSV99690568; called by muse, mutect2, varscan2
- ARL11 | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 141/435 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs369303916; called by muse, mutect2, varscan2
- ARL6IP4 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 131/370 reads (35%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.005); catalogued as rs199572570; called by muse, mutect2, varscan2
- ARMC4 | c.2522G>A p.R841H | Missense Mutation (SNP) | VAF 240/662 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs773324248, COSV59462487; called by muse, mutect2, varscan2
- ARMC4 | c.1666G>A p.A556T | Missense Mutation (SNP) | VAF 366/1023 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as rs1350513257; called by muse, mutect2, varscan2
- ARMC5 | c.1205G>A p.G402E | Missense Mutation (SNP) | VAF 41/261 reads (16%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.785); catalogued as rs372733855; called by muse, mutect2, varscan2
- ARMC6 | c.1137G>T p.Q379H (on ENST00000392336; = p.Q354H on NM_033415.4) | Missense Mutation (SNP) | VAF 119/284 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs1345124255; called by muse, mutect2, varscan2
- ARMC7 | c.362C>T p.T121M | Missense Mutation (SNP) | VAF 111/301 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs770124022; called by muse, mutect2, varscan2
- ARMH3 | c.1670G>A p.R557H | Missense Mutation (SNP) | VAF 169/512 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781574136; called by muse, mutect2, varscan2
- ARNT | c.487-5C>T | Splice Region (SNP) | VAF 150/397 reads (38%) | catalogued as rs199643789; called by muse, mutect2, varscan2
- ARRDC1 | c.655G>A p.V219I | Missense Mutation (SNP) | VAF 115/326 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.053); catalogued as rs376105916; called by muse, mutect2, varscan2
- ARRDC4 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 113/338 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs1202515242, COSV51418499; called by muse, mutect2, varscan2
- ARSF | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 166/229 reads (72%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as rs746758192, COSV104421277; called by muse, varscan2
- ARSF | c.1636G>A p.V546M | Missense Mutation (SNP) | VAF 40/560 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as COSV63840704; called by muse, mutect2
- ARSG | c.1093G>A p.V365M | Missense Mutation (SNP) | VAF 184/468 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as rs185381597; called by muse, varscan2
- ARVCF | c.2188G>A p.A730T | Missense Mutation (SNP) | VAF 167/496 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as rs202208069; called by muse, mutect2, varscan2
- ARVCF | c.1274G>A p.R425H | Missense Mutation (SNP) | VAF 76/269 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1480376529, COSV54267868; called by muse, mutect2, varscan2
- ARVCF | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 188/551 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs181094016, COSV54269496; called by muse, mutect2, varscan2
- ASAP1 | c.3286G>A p.V1096I | Missense Mutation (SNP) | VAF 133/472 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs764209195, COSV100727278, COSV63048856; called by muse, mutect2, varscan2
- ASAP1 | c.1217+1G>A p.X406_splice | Splice Site (SNP) | VAF 234/741 reads (32%) | catalogued as rs1225404314, COSV100727093; called by muse, mutect2, varscan2
- ASB1 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 84/303 reads (28%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.963); catalogued as rs760949441, COSV52826260; called by muse, mutect2
- ASB16 | c.10G>T p.E4* | Nonsense Mutation (SNP) | VAF 21/136 reads (15%) | catalogued as COSV53236414; called by muse, mutect2, varscan2
- ASB16 | c.1062+4C>T | Splice Region (SNP) | VAF 88/229 reads (38%) | catalogued as rs1349101588; called by muse, mutect2, varscan2
- ASH1L | c.5092G>A p.G1698R | Missense Mutation (SNP) | VAF 131/312 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs765286358; called by muse, mutect2, varscan2
- ASIC1 | c.1528G>A p.A510T | Missense Mutation (SNP) | VAF 133/414 reads (32%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as COSV99948157; called by muse, mutect2, varscan2
- ASIC5 | c.292G>A p.V98I | Missense Mutation (SNP) | VAF 621/1883 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.179); catalogued as rs1264822721; called by muse, mutect2, varscan2
- ASL | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 88/287 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1562742560, COSV59189626; called by muse, mutect2, varscan2
- ASPH | c.2062C>T p.R688* | Nonsense Mutation (SNP) | VAF 84/1082 reads (8%) | catalogued as rs755422939, COSV65248504; called by muse, mutect2
- ASPM | c.6407A>G p.Y2136C | Missense Mutation (SNP) | VAF 740/1983 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1478459684; called by mutect2, varscan2
- ASTN2 | c.1820A>G p.E607G (on ENST00000313400 / NM_001365069.1; = p.E556G on NM_014010.5) | Missense Mutation (SNP) | VAF 369/1118 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV57813521; called by muse, mutect2, varscan2
- ASTN2 | c.523G>A p.V175I | Missense Mutation (SNP) | VAF 127/614 reads (21%) | SIFT tolerated, low confidence (0.96); PolyPhen probably damaging (0.972); catalogued as rs371367035, COSV104400821; called by muse, varscan2
- ASZ1 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 110/304 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.097); catalogued as rs749959101; called by muse, varscan2
- ATG10 | c.*4+1G>A | Splice Site (SNP) | VAF 52/850 reads (6%) | catalogued as COSV56425357; called by muse, mutect2
- ATG101 | c.572A>G p.K191R | Missense Mutation (SNP) | VAF 136/473 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.042); catalogued as rs756360926; called by muse, mutect2, varscan2
- ATG14 | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 166/473 reads (35%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs761118635; called by muse, mutect2, varscan2
- ATG16L1 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 131/450 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1240290861; called by muse, varscan2
- ATG2A | c.4642C>T p.R1548W | Missense Mutation (SNP) | VAF 138/352 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV65967167; called by muse, mutect2, varscan2
- ATG2A | c.3529C>T p.R1177W | Missense Mutation (SNP) | VAF 75/192 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs543237129, COSV65965802; called by muse, mutect2, varscan2
- ATG2A | c.1516C>T p.R506W | Missense Mutation (SNP) | VAF 110/305 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as rs778851421; called by muse, mutect2, varscan2
- ATG2B | c.1787G>A p.R596Q | Missense Mutation (SNP) | VAF 385/1122 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs980451258, COSV63421820; called by muse, mutect2, varscan2
- ATG2B | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 231/721 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.46); catalogued as rs1445145372, COSV63425034; called by muse, mutect2, varscan2
- ATG4A | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 180/268 reads (67%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs140831275, COSV58968326; called by muse, mutect2, varscan2
- ATG7 | c.1741G>A p.V581M | Missense Mutation (SNP) | VAF 339/832 reads (41%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs764938921; called by muse, mutect2, varscan2
- ATG9B | c.2336C>T p.P779L | Missense Mutation (SNP) | VAF 240/715 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.091); catalogued as rs756553369, COSV99871276; called by muse, mutect2, varscan2
- ATIC | c.1634G>A p.R545Q | Missense Mutation (SNP) | VAF 270/868 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.423); catalogued as rs138166346; called by muse, mutect2, varscan2
- ATM | c.7228T>G p.F2410V | Missense Mutation (SNP) | VAF 308/978 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV53741392; called by muse, mutect2, varscan2
- ATP10A | c.4242G>T p.K1414N | Missense Mutation (SNP) | VAF 174/583 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.081); catalogued as rs1292490847, COSV63522601; called by muse, mutect2, varscan2
- ATP10A | c.2426G>A p.R809H | Missense Mutation (SNP) | VAF 335/938 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776829827, COSV63516508, COSV63516647, COSV63518546; called by muse, mutect2, varscan2
- ATP10A | c.625C>T p.R209W | Missense Mutation (SNP) | VAF 138/453 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs147157402, COSV63513255; called by muse, mutect2, varscan2
- ATP10D | c.1240dup p.M414Nfs*26 | Frame Shift Ins (INS) | VAF 252/1552 reads (16%) | catalogued as rs1440513677; called by mutect2, pindel, varscan2
- ATP11A | c.1380del p.S461Afs*23 | Frame Shift Del (DEL) | VAF 106/651 reads (16%) | catalogued as COSV52119662; called by mutect2, pindel, varscan2
- ATP11A | c.2465C>T p.A822V | Missense Mutation (SNP) | VAF 199/584 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368198251; called by muse, mutect2, varscan2
- ATP11A | c.2863G>A p.A955T | Missense Mutation (SNP) | VAF 227/623 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs145335126; called by muse, mutect2, varscan2
- ATP11B | c.1936C>T p.R646C | Missense Mutation (SNP) | VAF 304/887 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.052); catalogued as rs375942497; called by muse, mutect2, varscan2
- ATP13A1 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 119/378 reads (31%) | catalogued as rs144897534; called by muse, mutect2, varscan2
- ATP13A2 | c.880C>T p.R294W | Missense Mutation (SNP) | VAF 81/263 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs144898239; called by muse, mutect2, varscan2
- ATP1A1 | c.1022C>T p.T341M | Missense Mutation (SNP) | VAF 313/972 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759607882, COSV99814549; called by muse, mutect2, varscan2
- ATP1A2 | c.2879C>T p.A960V | Missense Mutation (SNP) | VAF 170/495 reads (34%) | SIFT tolerated (0.83); PolyPhen benign (0.011); catalogued as COSV100768270; called by muse, mutect2, varscan2
- ATP1A4 | c.1112C>T p.A371V | Missense Mutation (SNP) | VAF 326/950 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs369966942; called by muse, mutect2, varscan2
- ATP1B1 | c.698G>A p.G233D | Missense Mutation (SNP) | VAF 383/1070 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV63167064; called by muse, mutect2, varscan2
- ATP23 | c.722G>A p.R241Q | Missense Mutation (SNP) | VAF 218/607 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.46); catalogued as rs375771337; called by muse, varscan2
- ATP2A1 | c.2230G>A p.V744I | Missense Mutation (SNP) | VAF 91/271 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.465); catalogued as rs866421756, COSV100707138; called by muse, mutect2, varscan2
- ATP2A2 | c.2540C>T p.T847I | Missense Mutation (SNP) | VAF 157/461 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs868781956; called by muse, mutect2, varscan2
- ATP4A | c.1853G>A p.R618H | Missense Mutation (SNP) | VAF 179/523 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs149515531; called by muse, mutect2, varscan2
- ATP6AP2 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 242/342 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs745734335, COSV65797833, COSV65798347; called by muse, mutect2, varscan2
- ATP6V0A4 | c.2413G>A p.A805T | Missense Mutation (SNP) | VAF 139/462 reads (30%) | SIFT tolerated (0.45); PolyPhen probably damaging (1); catalogued as rs369999617; called by muse, mutect2, varscan2
- ATP6V0A4 | c.589G>A p.V197M | Missense Mutation (SNP) | VAF 150/450 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.626); catalogued as rs756026017; called by muse, varscan2
- ATP6V1B1 | c.175-4C>T | Splice Region (SNP) | VAF 81/560 reads (14%) | catalogued as rs782511029; called by muse, mutect2, varscan2
- ATP7B | c.4163C>T p.A1388V | Missense Mutation (SNP) | VAF 283/790 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs371458882; ClinVar: uncertain significance; called by muse, varscan2
- ATP8A1 | c.2695-8C>T | Splice Region (SNP) | VAF 443/1317 reads (34%) | catalogued as rs375459418; called by muse, mutect2, varscan2
- ATP8A1 | c.2272C>T p.R758* | Nonsense Mutation (SNP) | VAF 475/1361 reads (35%) | catalogued as rs1198813685; called by muse, mutect2, varscan2
- ATP8B1 | c.3716C>T p.A1239V | Missense Mutation (SNP) | VAF 144/383 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs767343941, COSV52177486; called by muse, mutect2, varscan2
- ATP8B2 | c.628C>T p.R210C (on ENST00000672630; = p.R177C on NM_001005855.2) | Missense Mutation (SNP) | VAF 207/606 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs768000646; called by muse, mutect2, varscan2
- ATP8B2 | c.1597G>A p.V533I (on ENST00000672630; = p.V500I on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 110/571 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59245657; called by muse, mutect2, varscan2
- ATP9B | c.2116C>T p.R706* | Nonsense Mutation (SNP) | VAF 158/508 reads (31%) | catalogued as COSV56948983; called by muse, varscan2
- ATPSCKMT | c.481G>A p.G161S | Missense Mutation (SNP) | VAF 168/459 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54727210, COSV99725850; called by muse, mutect2, varscan2
- ATR | c.6197G>A p.R2066Q | Missense Mutation (SNP) | VAF 254/744 reads (34%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.656); catalogued as rs886058052, COSV63394502; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATR | c.5374G>A p.A1792T | Missense Mutation (SNP) | VAF 246/748 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.16); catalogued as rs1400794830; called by muse, varscan2
- ATR | c.3819G>T p.K1273N | Missense Mutation (SNP) | VAF 277/840 reads (33%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.937); catalogued as COSV63389136; called by mutect2, varscan2
- ATR | c.2947G>A p.D983N | Missense Mutation (SNP) | VAF 319/957 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.874); catalogued as rs537845660, COSV63387210, COSV63388887; called by muse, mutect2, varscan2
- ATRIP | c.1841C>T p.A614V | Missense Mutation (SNP) | VAF 106/387 reads (27%) | SIFT tolerated (0.97); PolyPhen benign (0.001); catalogued as rs138163219; called by muse, mutect2, varscan2
- ATRN | c.1949C>T p.A650V | Missense Mutation (SNP) | VAF 65/960 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as rs748401480, COSV99497413; called by muse, mutect2
- ATRNL1 | c.199G>A p.G67S | Missense Mutation (SNP) | VAF 29/348 reads (8%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs1457418999; called by muse, mutect2
- ATRNL1 | c.4037C>T p.A1346V | Missense Mutation (SNP) | VAF 298/962 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1228477997, COSV58100368; called by muse, mutect2, varscan2
- ATRX | c.6862C>T p.R2288C | Missense Mutation (SNP) | VAF 315/430 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs782342279; called by muse, mutect2, varscan2
- ATRX | c.3145del p.I1049* | Frame Shift Del (DEL) | VAF 477/825 reads (58%) | catalogued as COSV64885073; called by mutect2, pindel, varscan2
- ATXN2L | c.2666C>T p.A889V | Missense Mutation (SNP) | VAF 149/437 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs763582122, COSV57376698; called by muse, mutect2, varscan2
- ATXN7L2 | c.1000C>T p.R334C | Missense Mutation (SNP) | VAF 225/562 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs1397595382; called by muse, mutect2, varscan2
- ATXN7L2 | c.1906C>T p.L636F | Missense Mutation (SNP) | VAF 211/532 reads (40%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.023); catalogued as rs761349734; called by muse, mutect2, varscan2
- AVIL | c.403C>T p.R135W | Missense Mutation (SNP) | VAF 187/461 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770023170; called by muse, mutect2, varscan2
- AVPR1B | c.833G>A p.R278Q | Missense Mutation (SNP) | VAF 141/472 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); catalogued as rs369649163; called by muse, mutect2, varscan2
- AWAT2 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 351/472 reads (74%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs776963283, COSV52143081; called by muse, mutect2, varscan2
- AWAT2 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 275/378 reads (73%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs769015502; called by muse, mutect2, varscan2
- AXIN2 | c.1780G>A p.A594T | Missense Mutation (SNP) | VAF 221/596 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs876660965; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AXL | c.1109C>T p.A370V | Missense Mutation (SNP) | VAF 52/654 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.015); catalogued as rs767925068; called by muse, mutect2
- B3GALT4 | c.1105C>T p.R369W | Missense Mutation (SNP) | VAF 125/322 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs761609610; called by muse, mutect2, varscan2
- B3GAT1 | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 112/274 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56997817; called by muse, mutect2, varscan2
- B3GNT3 | c.637G>T p.V213F | Missense Mutation (SNP) | VAF 91/284 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100427648; called by muse, mutect2, varscan2
- B3GNT6 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 116/299 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as rs782714525, COSV62828732; called by muse, mutect2, varscan2
- B3GNT8 | c.862G>T p.G288* | Nonsense Mutation (SNP) | VAF 94/207 reads (45%) | catalogued as COSV99524571, COSV99524889; called by muse, mutect2, varscan2
- B3GNT8 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 87/273 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs768710783; called by muse, mutect2, varscan2
- B3GNTL1 | c.608C>T p.P203L | Missense Mutation (SNP) | VAF 96/344 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as rs572010424; called by muse, mutect2, varscan2
- B4GALNT4 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 100/290 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs747752780; called by muse, mutect2, varscan2
- B4GALNT4 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 54/181 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.182); catalogued as COSV57326114; called by muse, mutect2, varscan2
- B4GALNT4 | c.2093C>T p.S698L | Missense Mutation (SNP) | VAF 56/168 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs755485725; called by muse, varscan2
- B4GALT6 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 85/1040 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs901456078, COSV52704419; called by muse, mutect2
- BAAT | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 274/882 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as rs764771610, COSV52291279; called by muse, mutect2, varscan2
- BACH2 | c.1957C>T p.R653C | Missense Mutation (SNP) | VAF 343/1009 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57590039, COSV57592010; called by muse, mutect2, varscan2
- BACH2 | c.1430C>T p.S477L | Missense Mutation (SNP) | VAF 110/319 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.204); catalogued as rs761051258, COSV57588651; called by muse, mutect2, varscan2
- BACH2 | c.509C>T p.T170M | Missense Mutation (SNP) | VAF 217/648 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as COSV57587489; called by muse, varscan2
- BACH2 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 190/574 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as rs1393834853, COSV100000252, COSV57601946; called by muse, varscan2
- BAG4 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 122/379 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs147141531; called by muse, mutect2, varscan2
- BAG6 | c.2630G>A p.R877Q (on ENST00000676571; = p.R830Q on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 134/446 reads (30%) | SIFT tolerated (0.97); PolyPhen benign (0.042); catalogued as rs150629776; called by muse, varscan2
- BAG6 | c.1286C>T p.P429L | Missense Mutation (SNP) | VAF 58/523 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.207); catalogued as rs756796442; called by muse, mutect2, varscan2
- BAG6 | c.1040G>A p.R347Q | Missense Mutation (SNP) | VAF 175/461 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771400122, COSV52992058; called by muse, mutect2, varscan2
- BAHCC1 | c.4496G>A p.R1499H | Missense Mutation (SNP) | VAF 69/203 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.633); catalogued as rs782024906; called by muse, varscan2
- BAHD1 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 82/284 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs578160651, COSV69083688; called by muse, varscan2
- BAHD1 | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 86/199 reads (43%) | SIFT tolerated (0.8); PolyPhen benign (0.015); catalogued as rs1211115318; called by muse, varscan2
- BAIAP2 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 153/474 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs146668397; called by muse, mutect2, varscan2
- BANF1 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 147/460 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.051); catalogued as COSV56463394; called by muse, mutect2, varscan2
- BANK1 | c.2158C>T p.R720* | Nonsense Mutation (SNP) | VAF 355/1120 reads (32%) | catalogued as rs761282774, COSV59848357; called by muse, mutect2, varscan2
- BANP | c.334C>T p.R112* (on ENST00000286122; = p.R120* on NM_017869.4) | Nonsense Mutation (SNP) | VAF 132/424 reads (31%) | catalogued as rs1252212677; called by muse, mutect2, varscan2
- BAZ1A | c.3448C>T p.R1150C | Missense Mutation (SNP) | VAF 254/728 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057335359; called by muse, mutect2, varscan2
- BAZ2A | c.4933C>T p.R1645C | Missense Mutation (SNP) | VAF 145/451 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1053778342; called by muse, mutect2, varscan2
- BAZ2B | c.4103C>T p.A1368V | Missense Mutation (SNP) | VAF 282/852 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as rs764609647, COSV58609868; called by muse, mutect2, varscan2
- BAZ2B | c.3145C>T p.R1049* | Nonsense Mutation (SNP) | VAF 564/1740 reads (32%) | catalogued as COSV54276779; called by muse, mutect2, varscan2
- BBS5 | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 158/526 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs756421732, COSV54751698; called by muse, mutect2, varscan2
- BBX | c.1480G>A p.A494T | Missense Mutation (SNP) | VAF 615/1777 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1180791665, COSV57884802; called by muse, mutect2, varscan2
- BCAN | c.2635G>A p.A879T | Missense Mutation (SNP) | VAF 79/459 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.1); catalogued as rs1183015641; called by muse, mutect2, varscan2
- BCKDK | c.717-4G>A | Splice Region (SNP) | VAF 101/312 reads (32%) | catalogued as rs200045337, COSV54890388; called by muse, varscan2
- BCL11A | c.670C>T p.R224C (on ENST00000335712 / NM_001365609.1; = p.R258C on NM_018014.4) | Missense Mutation (SNP) | VAF 52/794 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1489022670, COSV59623668; called by muse, mutect2
- BCL11B | c.2252G>A p.R751H (on ENST00000357195 / NM_001282237.2; = p.R680H on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/377 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as rs1353912068; called by muse, mutect2
- BCL11B | c.1069G>A p.D357N (on ENST00000357195 / NM_001282237.2; = p.D286N on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 178/501 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as rs1315805416; called by muse, varscan2
- BCL11B | c.1063G>A p.A355T (on ENST00000357195 / NM_001282237.2; = p.A284T on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 179/482 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.186); catalogued as COSV61738589; called by muse, varscan2
- BCL2L10 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 63/364 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV99548571; called by muse, mutect2, varscan2
- BCL2L11 | c.317C>T p.A106V (on ENST00000393256 / NM_138621.5; = p.A46V on NM_006538.5) | Missense Mutation (SNP) | VAF 232/731 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.379); catalogued as rs773443902; called by muse, mutect2, varscan2
- BCL2L13 | c.1220C>T p.T407M | Missense Mutation (SNP) | VAF 258/706 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs1010026322; called by muse, mutect2, varscan2
- BCL6 | c.1334G>A p.R445Q | Missense Mutation (SNP) | VAF 304/913 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.174); catalogued as rs761002552; called by muse, mutect2, varscan2
- BCL7B | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 217/613 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as COSV99790347; called by muse, mutect2, varscan2
- BCL9 | c.1681C>T p.R561C | Missense Mutation (SNP) | VAF 210/597 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs375006061, COSV52345214; called by muse, mutect2, varscan2
- BCL9 | c.2527C>T p.R843W | Missense Mutation (SNP) | VAF 34/494 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs1054803579, COSV52343883; called by muse, mutect2
- BCL9 | c.3112G>A p.D1038N | Missense Mutation (SNP) | VAF 483/1281 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1553205594; called by muse, varscan2
- BCL9L | c.3874G>A p.A1292T | Missense Mutation (SNP) | VAF 86/261 reads (33%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs771126846, COSV52684875; called by muse, mutect2, varscan2
- BCO1 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 143/431 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as rs373952238; called by muse, mutect2, varscan2
- BCO1 | c.1603C>T p.R535W | Missense Mutation (SNP) | VAF 211/540 reads (39%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs770313011, COSV50731040; called by muse, mutect2, varscan2
- BCO2 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 216/653 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1458283378; called by muse, mutect2, varscan2
- BCOR | c.4766G>A p.R1589H (on ENST00000378444 / NM_001123385.2; = p.R1555H on NM_017745.6) | Missense Mutation (SNP) | VAF 272/367 reads (74%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs367859441; ClinVar: not provided; called by muse, mutect2, varscan2
- BCOR | c.31G>A p.V11I | Missense Mutation (SNP) | VAF 170/240 reads (71%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.352); catalogued as rs772165033, COSV60702882; called by muse, varscan2
- BCR | c.1471G>T p.D491Y | Missense Mutation (SNP) | VAF 95/333 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100006622; called by muse, mutect2, varscan2
- BDNF | c.685C>T p.R229* | Nonsense Mutation (SNP) | VAF 356/1082 reads (33%) | catalogued as rs772989712, COSV59234017; called by muse, varscan2
- BECN2 | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 35/205 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs755547837; called by muse, mutect2, varscan2
- BEND2 | c.193C>T p.P65S | Missense Mutation (SNP) | VAF 336/487 reads (69%) | SIFT tolerated (0.65); PolyPhen benign (0.101); catalogued as COSV66217614; called by muse, mutect2, varscan2
- BEND3 | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 25/495 reads (5%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1213131224; called by muse, mutect2
- BEND3 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 104/306 reads (34%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.007); catalogued as rs1554231907, COSV64682444; called by muse, mutect2, varscan2
- BEND4 | c.1496C>T p.A499V | Missense Mutation (SNP) | VAF 357/1073 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs759939750, COSV101549753; called by muse, mutect2, varscan2
- BEND4 | c.1237C>T p.R413W | Missense Mutation (SNP) | VAF 381/1168 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs760937059; called by muse, mutect2, varscan2
- BEND5 | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 279/839 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs776357116, COSV65718000; called by muse, mutect2, varscan2
- BFSP2 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 176/391 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.195); catalogued as rs774937998, COSV100183488; called by muse, mutect2, varscan2
- BFSP2 | c.1162C>T p.R388C | Missense Mutation (SNP) | VAF 294/774 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as COSV56589533; called by muse, mutect2, varscan2
- BICD2 | c.1990G>A p.A664T | Missense Mutation (SNP) | VAF 36/372 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.192); catalogued as rs752300430, COSV63548540; called by muse, mutect2
- BICD2 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 232/711 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.341); catalogued as rs1338473700, COSV63548221; called by muse, mutect2, varscan2
- BICD2 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 206/552 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1243468345; called by muse, mutect2, varscan2
- BIN3 | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 124/412 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs778507963, COSV52385035; called by muse, mutect2, varscan2
- BIRC6 | c.12646G>A p.V4216I | Missense Mutation (SNP) | VAF 509/1406 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs1290135066, COSV101427822; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.620G>A p.R207Q | Missense Mutation (SNP) | VAF 268/780 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs775945195; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4282G>A p.D1428N | Missense Mutation (SNP) | VAF 265/861 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); catalogued as rs747456426; called by muse, mutect2, varscan2
- BLM | c.2453G>A p.R818H | Missense Mutation (SNP) | VAF 212/572 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs780514723; ClinVar: uncertain significance; called by muse, varscan2
- BLVRA | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 231/715 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs867045095; called by muse, mutect2, varscan2
- BMP1 | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 84/291 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs781010518; called by muse, mutect2, varscan2
- BMP2 | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 375/1051 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66578549; called by muse, varscan2
- BMP4 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 366/1134 reads (32%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.979); catalogued as rs777406477, COSV99816957; called by muse, mutect2
- BMP4 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 171/976 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as rs1418818779; called by muse, mutect2, varscan2
- BMP6 | c.1351G>A p.A451T | Missense Mutation (SNP) | VAF 354/1039 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs377711135; called by muse, mutect2, varscan2
- BMP7 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 326/892 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV67779434; called by muse, varscan2
- BMPR2 | c.2528C>T p.A843V | Missense Mutation (SNP) | VAF 279/878 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as COSV101001222; called by muse, mutect2, varscan2
- BNC1 | c.2030G>A p.R677H | Missense Mutation (SNP) | VAF 58/882 reads (7%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs527423780, COSV100597328; called by muse, mutect2
- BNC1 | c.1478G>A p.R493H | Missense Mutation (SNP) | VAF 296/827 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs779416407, COSV61759033; called by muse, mutect2, varscan2
- BOC | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 383/1145 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.099); catalogued as rs565408329, COSV56352611; called by muse, varscan2
- BOD1L1 | c.2045G>A p.R682H | Missense Mutation (SNP) | VAF 491/1306 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs1298034837, COSV50006319, COSV50019410; called by muse, mutect2, varscan2
- BOK | c.222C>T p.G74= | Splice Region (SNP) | VAF 112/320 reads (35%) | catalogued as rs1435050836; called by muse, mutect2, varscan2
- BPNT2 | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 407/1199 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.103); catalogued as rs747764009, COSV52906615; called by muse, mutect2, varscan2
- BPNT2 | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 163/427 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.476); catalogued as rs751845541; called by muse, mutect2, varscan2
- BPTF | c.2341C>T p.R781W | Missense Mutation (SNP) | VAF 233/785 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866805175, COSV100074830; called by muse, mutect2, varscan2
- BRAT1 | c.1644G>T p.Q548H | Missense Mutation (SNP) | VAF 102/278 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as rs756528477, COSV100500755; called by muse, mutect2, varscan2
- BRCA1 | c.1255G>A p.V419I | Missense Mutation (SNP) | VAF 204/641 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.649); catalogued as rs876658873, CD984129; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA1 | c.994C>T p.R332W | Missense Mutation (SNP) | VAF 278/803 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs80357176, COSV58793350; ClinVar: uncertain significance / likely benign; called by muse, varscan2
- BRCA2 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 285/795 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as rs80358603, CM024725, COSV66456384; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.8092G>A p.A2698T | Missense Mutation (SNP) | VAF 315/903 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs80359052, COSV66455423; ClinVar: conflicting interpretations of pathogenicity / uncertain significance / likely benign; called by muse, mutect2, varscan2
- BRCA2 | c.8755-1G>T p.X2919_splice | Splice Site (SNP) | VAF 371/926 reads (40%) | catalogued as CS994298; called by muse, mutect2, varscan2
- BRD4 | c.3775C>T p.R1259C | Missense Mutation (SNP) | VAF 58/320 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1187497598, COSV99650130; called by muse, varscan2
- BRD4 | c.587T>C p.V196A | Missense Mutation (SNP) | VAF 178/586 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV54583675; called by muse, mutect2, varscan2
- BRD9 | c.1627G>A p.G543S | Missense Mutation (SNP) | VAF 195/563 reads (35%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as rs1400151697, COSV60247841; called by muse, mutect2, varscan2
- BRF2 | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 176/499 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1251717807, COSV55105084; called by muse, mutect2, varscan2
- BRICD5 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 67/194 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.029); catalogued as rs746698270; called by muse, mutect2, varscan2
- BRICD5 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 128/344 reads (37%) | SIFT tolerated (0.85); PolyPhen benign (0.106); catalogued as rs200062503; called by muse, varscan2
- BRINP1 | c.1376G>A p.G459D | Missense Mutation (SNP) | VAF 61/616 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747785836; called by muse, mutect2, varscan2
- BRINP3 | c.1588C>T p.R530C | Missense Mutation (SNP) | VAF 132/1496 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV66522433; called by muse, mutect2
- BRPF1 | c.1316G>A p.R439H | Missense Mutation (SNP) | VAF 274/738 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs771693624, COSV100121388; called by muse, varscan2
- BRPF1 | c.2855C>T p.S952L | Missense Mutation (SNP) | VAF 122/420 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs551623538; called by muse, mutect2, varscan2
- BRPF3 | c.1565G>A p.R522H | Missense Mutation (SNP) | VAF 336/1037 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs200249910; called by muse, mutect2, varscan2
- BRSK1 | c.1180C>T p.R394* | Nonsense Mutation (SNP) | VAF 94/286 reads (33%) | catalogued as rs757051523; called by muse, mutect2, varscan2
- BRWD1 | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 139/818 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs759416383, COSV60904585; called by muse, mutect2, varscan2
- BSN | c.3203G>A p.R1068H | Missense Mutation (SNP) | VAF 228/634 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1336122554; called by muse, mutect2, varscan2
- BSN | c.8836C>T p.R2946W | Missense Mutation (SNP) | VAF 152/471 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs765703453; called by muse, mutect2, varscan2
- BSND | c.958G>T p.G320C | Missense Mutation (SNP) | VAF 150/490 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.912); catalogued as rs1268170152; called by muse, mutect2, varscan2
- BSPRY | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 149/423 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs368306479, COSV100949481; called by muse, mutect2, varscan2
- BTAF1 | c.3383G>A p.R1128H | Missense Mutation (SNP) | VAF 322/889 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs763678052, COSV56434467; called by muse, mutect2, varscan2
- BTBD6 | c.1054C>T p.R352W | Missense Mutation (SNP) | VAF 34/242 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs142466787; called by muse, mutect2, varscan2
- BTBD7 | c.2738C>T p.S913L | Missense Mutation (SNP) | VAF 200/545 reads (37%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.038); catalogued as rs569825061; called by muse, mutect2, varscan2
- BTBD8 | c.1099C>A p.L367I | Missense Mutation (SNP) | VAF 245/884 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.283); catalogued as COSV100730091; called by muse, mutect2, varscan2
- BTBD9 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 454/1290 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs773802163; called by muse, mutect2, varscan2
- BTK | c.938G>A p.G313D | Missense Mutation (SNP) | VAF 282/415 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD951635; called by muse, mutect2, varscan2
- BTN1A1 | c.1259G>A p.R420H | Missense Mutation (SNP) | VAF 253/716 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.036); catalogued as rs202063334; called by muse, mutect2, varscan2
- BTN2A2 | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 330/1001 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs375285642; called by muse, mutect2, varscan2
- BTN3A1 | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 220/632 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.825); catalogued as rs199668049, COSV50024953; called by muse, varscan2
- BTRC | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 203/547 reads (37%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.835); catalogued as rs752077302, COSV64561145; called by muse, mutect2, varscan2
- BTRC | c.1537C>T p.R513* (on ENST00000370187 / NM_033637.4; = p.R477* on NM_003939.5) | Nonsense Mutation (SNP) | VAF 177/527 reads (34%) | catalogued as rs568788208, COSV64579105; called by muse, mutect2, varscan2
- C10orf105 | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 136/407 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs936905416; called by muse, mutect2, varscan2
- C10orf71 | c.1792G>A p.A598T | Missense Mutation (SNP) | VAF 81/1070 reads (8%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs769272748, COSV60509325; called by muse, mutect2
- C10orf71 | c.2689C>T p.P897S | Missense Mutation (SNP) | VAF 170/482 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.175); catalogued as rs1440217086; called by muse, mutect2, varscan2
- C10orf90 | c.817G>A p.V273I | Missense Mutation (SNP) | VAF 410/894 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs1215727661, COSV99504499; called by muse, mutect2, varscan2
- C11orf1 | c.166C>T p.R56* | Nonsense Mutation (SNP) | VAF 40/814 reads (5%) | catalogued as rs782010241, COSV52787941; called by muse, mutect2
- C11orf40 | n.307C>A | Splice Region (SNP) | VAF 240/721 reads (33%) | catalogued as rs1004801895; called by muse, mutect2, varscan2
- C11orf42 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 312/873 reads (36%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.168); catalogued as rs764844053; called by muse, mutect2, varscan2
- C11orf42 | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 190/527 reads (36%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.005); catalogued as COSV56414742; called by muse, mutect2, varscan2
- C11orf68 | c.545G>A p.R182H (on ENST00000530188; = p.R223H on NM_031450.4) | Missense Mutation (SNP) | VAF 53/167 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.21); catalogued as rs755554643; called by muse, varscan2
- C11orf68 | c.505C>T p.R169C (on ENST00000530188; = p.R210C on NM_031450.4) | Missense Mutation (SNP) | VAF 65/207 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV56988053; called by muse, varscan2
- C12orf42 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 86/637 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.083); catalogued as rs760840304; called by muse, mutect2, varscan2
- C12orf66 | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 185/569 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs772154676, COSV61322239; called by muse, mutect2, varscan2
- C12orf71 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 161/409 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.307); catalogued as rs765971425; called by muse, mutect2, varscan2
- C14orf93 | c.1328G>A p.R443H | Missense Mutation (SNP) | VAF 105/302 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs139611172; called by muse, mutect2, varscan2
- C15orf39 | c.1474G>A p.A492T | Missense Mutation (SNP) | VAF 102/303 reads (34%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs541739163; called by muse, mutect2, varscan2
- C15orf39 | c.2768G>A p.R923H | Missense Mutation (SNP) | VAF 110/355 reads (31%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.985); catalogued as rs368832740; called by muse, mutect2, varscan2
- C16orf70 | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 199/622 reads (32%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.928); catalogued as rs149407168; called by muse, mutect2, varscan2
- C16orf89 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 216/636 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs748422574; called by muse, mutect2, varscan2
- C16orf90 | c.551G>A p.R184H (on ENST00000399645 / NM_001353385.2; = p.R175H on NM_001080524.2) | Missense Mutation (SNP) | VAF 109/296 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.067); catalogued as rs371199813; called by muse, mutect2, varscan2
- C16orf92 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 74/322 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs370643656, COSV54228068; called by muse, varscan2
- C17orf80 | c.1106C>T p.S369L | Missense Mutation (SNP) | VAF 209/614 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as rs757774323; called by muse, mutect2, varscan2
- C19orf18 | c.428G>A p.R143K | Missense Mutation (SNP) | VAF 131/430 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV58708295; called by muse, mutect2, varscan2
- C19orf57 | c.199G>A p.V67I | Missense Mutation (SNP) | VAF 92/258 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.117); catalogued as rs765683700, COSV100694757; called by muse, mutect2, varscan2
- C1QB | c.544C>T p.L182F | Missense Mutation (SNP) | VAF 204/537 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); catalogued as rs923958953; called by muse, mutect2, varscan2
- C1QTNF4 | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 63/188 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV56784508; called by muse, mutect2, varscan2
- C1QTNF8 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 79/242 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1307677470; called by muse, mutect2, varscan2
- C1orf43 | c.533G>A p.R178H (on ENST00000368521 / NM_001297718.2; = p.R144H on NM_015449.4) | Missense Mutation (SNP) | VAF 173/500 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1232404520; called by muse, mutect2, varscan2
- C1orf43 | c.494G>A p.R165H (on ENST00000368521 / NM_001297718.2; = p.R131H on NM_015449.4) | Missense Mutation (SNP) | VAF 214/544 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.795); catalogued as COSV62966011; called by muse, varscan2
- C1orf50 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 128/801 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.722); catalogued as COSV100998110; called by muse, mutect2, varscan2
- C20orf144 | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 120/574 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs370447346; called by muse, varscan2
- C20orf144 | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 140/346 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.291); catalogued as rs942084610; called by muse, varscan2
- C20orf173 | c.68G>A p.S23N | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs41307151; called by muse, mutect2, varscan2
- C22orf15 | c.220C>T p.R74* | Nonsense Mutation (SNP) | VAF 120/362 reads (33%) | catalogued as rs775602012; called by muse, mutect2, varscan2
- C2CD2 | c.2028G>T p.K676N | Missense Mutation (SNP) | VAF 237/691 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.286); catalogued as COSV100298133; called by muse, mutect2, varscan2
- C2CD4C | c.112T>C p.Y38H | Missense Mutation (SNP) | VAF 92/255 reads (36%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.948); catalogued as rs1478180054; called by muse, mutect2, varscan2
- C2CD4D | c.1040C>T p.A347V | Missense Mutation (SNP) | VAF 125/372 reads (34%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); catalogued as COSV63256106; called by muse, mutect2, varscan2
- C2orf76 | c.32G>A p.R11H | Missense Mutation (SNP) | VAF 225/621 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs771993808, COSV100601741; called by muse, mutect2, varscan2
- C2orf92 | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 198/710 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as rs1048541852, COSV101491199; called by muse, mutect2
- C3 | c.4828G>A p.D1610N | Missense Mutation (SNP) | VAF 151/547 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1204648676; called by muse, mutect2, varscan2
- C3 | c.3365C>T p.A1122V | Missense Mutation (SNP) | VAF 155/487 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV55573977; called by muse, mutect2, varscan2
- C3 | c.3070G>A p.A1024T | Missense Mutation (SNP) | VAF 113/273 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.926); catalogued as rs1421843172, COSV55577235; called by muse, varscan2
- C3orf18 | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 151/432 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.314); catalogued as rs142961797; called by muse, mutect2, varscan2
15,307 further variants in this file (9,017 protein-altering or splice-affecting, 3,448 silent, 2,842 other) are not listed here.
